Somatic mutation profile of tumor specimen C3L-04732-02 (aliquot CPT0297220006) from CPTAC case C3L-04732, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 83.1 years (30,365 days).
Specimen C3L-04732-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 269d7c6a-21e2-4aa3-a7b9-7cb98688a236.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04732-31 (Blood Derived Normal), aliquot CPT0297290002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/811b2c5b-3054-4f62-a2c7-fa20d351a4f3

The open-access MAF lists 1,127 somatic variants for this specimen: 733 protein-altering or splice-affecting, 359 silent, 35 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 662, Silent 359, Nonsense Mutation 47, Intron 24, Splice Region 11, Splice Site 5, 3'UTR 5, Translation Start Site 4, Frame Shift Del 3, 5'Flank 2, 5'UTR 2, RNA 1.

Variants (750 of 1,127; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1918G>A p.V640M (on ENST00000288602 / NM_001374244.1; = p.V600M on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 241/414 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs121913378, COSV56066607, COSV56075762, COSV56124012, COSV56152883; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MAP2K1 | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 155/448 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397516792, CM071852, CM073191, COSV61068422, COSV61068985, COSV61070219; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SOX10 | c.425G>A p.W142* | Nonsense Mutation (SNP) | VAF 110/303 reads (36%) | catalogued as rs886039664; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SPINK5 | c.2215C>T p.Q739* | Nonsense Mutation (SNP) | VAF 92/146 reads (63%) | catalogued as rs766028970; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 72/239 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1330988062; called by muse, mutect2, varscan2
- ABTB1 | c.1183C>T p.R395W (on ENST00000232744 / NM_172027.3; = p.R253W on NM_032548.3) | Missense Mutation (SNP) | VAF 159/426 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs751809260, COSV51739855; called by muse, mutect2, varscan2
- ACAD10 | c.3028C>T p.R1010C | Missense Mutation (SNP) | VAF 103/265 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.117); catalogued as rs746299861, COSV58160438; called by muse, mutect2, varscan2
- ACP6 | c.313C>T p.P105S | Missense Mutation (SNP) | VAF 164/376 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.068); catalogued as rs781952488; called by muse, mutect2, varscan2
- ACTRT1 | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 196/255 reads (77%) | SIFT tolerated (0.07); PolyPhen benign (0.146); catalogued as COSV64419728; called by muse, mutect2, varscan2
- ADAM28 | c.1990C>T p.H664Y | Missense Mutation (SNP) | VAF 97/163 reads (60%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs374347801; called by muse, mutect2, varscan2
- ADAM29 | c.913G>A p.G305R | Missense Mutation (SNP) | VAF 153/415 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.449); catalogued as COSV63662277; called by muse, mutect2, varscan2
- ADAM29 | c.914G>A p.G305E | Missense Mutation (SNP) | VAF 152/415 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as rs267600089, COSV63664596; called by muse, mutect2, varscan2
- ADAMDEC1 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 77/139 reads (55%) | SIFT tolerated (0.7); PolyPhen benign (0.065); catalogued as COSV56474828; called by muse, mutect2, varscan2
- ADGRA3 | c.2719C>T p.P907S | Missense Mutation (SNP) | VAF 91/259 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.266); catalogued as rs190503014; called by muse, mutect2, varscan2
- AHI1 | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 104/163 reads (64%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs766052712, COSV55627834; called by muse, mutect2, varscan2
- AL590132.1 | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 143/392 reads (36%) | SIFT tolerated, low confidence (0.38); catalogued as rs954104044; called by muse, mutect2, varscan2
- ALB | c.881C>T p.S294L | Missense Mutation (SNP) | VAF 119/375 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.041); catalogued as rs774294755, COSV55738750, COSV55739357; called by muse, mutect2, varscan2
- ALK | c.2807G>A p.G936E | Missense Mutation (SNP) | VAF 51/136 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66565516; called by muse, mutect2, varscan2
- AMER1 | c.1289C>T p.S430F | Missense Mutation (SNP) | VAF 234/316 reads (74%) | SIFT tolerated (0.2); PolyPhen benign (0.046); catalogued as COSV57655475; called by muse, mutect2, varscan2
- AMIGO2 | c.1030C>T p.H344Y | Missense Mutation (SNP) | VAF 181/419 reads (43%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV56974322; called by muse, mutect2, varscan2
- ANKEF1 | c.1646C>T p.A549V | Missense Mutation (SNP) | VAF 72/187 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV65692785; called by muse, mutect2, varscan2
- ANKRD11 | c.6919C>T p.P2307S | Missense Mutation (SNP) | VAF 118/351 reads (34%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs575642464; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- ANO4 | c.2708C>T p.S903L (on ENST00000392977 / NM_001286615.2; = p.S868L on NM_178826.4) | Missense Mutation (SNP) | VAF 141/387 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV54587306; called by muse, mutect2, varscan2
- ANPEP | c.1517C>T p.T506I | Missense Mutation (SNP) | VAF 127/344 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.091); catalogued as rs778343745; called by muse, mutect2, varscan2
- AOAH | c.482C>T p.S161L | Missense Mutation (SNP) | VAF 114/285 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as COSV51742240; called by muse, mutect2, varscan2
- APBB1IP | c.836G>A p.G279E | Missense Mutation (SNP) | VAF 51/201 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.038); catalogued as COSV100881955; called by muse, mutect2, varscan2
- APC | c.4085C>T p.S1362F | Missense Mutation (SNP) | VAF 140/233 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.384); catalogued as COSV57323094; called by muse, mutect2, varscan2
- AREL1 | c.1999C>T p.R667W | Missense Mutation (SNP) | VAF 128/318 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758705986, COSV62667762; called by muse, mutect2, varscan2
- ARHGAP25 | c.1038G>A p.M346I (on ENST00000409202 / NM_001007231.3; = p.M338I on NM_014882.3) | Missense Mutation (SNP) | VAF 96/249 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV54910432; called by muse, mutect2, varscan2
- ARHGAP26 | c.2357T>C p.V786A | Missense Mutation (SNP) | VAF 99/197 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs757256218; called by muse, mutect2, varscan2
- ARID1A | c.1457C>T p.S486F | Missense Mutation (SNP) | VAF 177/476 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV61376199; called by muse, mutect2, varscan2
- ARMC4 | c.1987G>A p.E663K | Missense Mutation (SNP) | VAF 62/184 reads (34%) | SIFT tolerated (0.52); PolyPhen benign (0.021); catalogued as rs765376476, COSV59461397; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ASCC2 | c.1903G>A p.E635K | Missense Mutation (SNP) | VAF 76/206 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as rs144123603; called by muse, mutect2, varscan2
- ASNSD1 | c.995C>T p.S332F | Missense Mutation (SNP) | VAF 127/362 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1354767830; called by muse, mutect2, varscan2
- ASTN1 | c.550C>T p.R184C | Missense Mutation (SNP) | VAF 158/413 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs767625006, COSV56070602; called by muse, mutect2, varscan2
- ATAD2 | c.3499C>T p.R1167C | Missense Mutation (SNP) | VAF 176/329 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs772123752; called by muse, mutect2, varscan2
- ATP10D | c.2234G>A p.R745Q | Missense Mutation (SNP) | VAF 163/440 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1162198061, COSV99905450; called by muse, mutect2, varscan2
- ATP1A3 | c.488C>T p.S163F (on ENST00000545399 / NM_001256214.2; = p.S150F on NM_152296.5) | Missense Mutation (SNP) | VAF 77/215 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100132337; called by muse, mutect2, varscan2
- ATP8B4 | c.3484A>G p.T1162A | Missense Mutation (SNP) | VAF 188/487 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1380465886; called by muse, mutect2, varscan2
- BCL2L12 | c.422C>T p.S141F | Missense Mutation (SNP) | VAF 201/532 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.466); catalogued as rs972656772, COSV99880954; called by muse, mutect2, varscan2
- BCLAF3 | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 233/311 reads (75%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV61413448; called by muse, mutect2, varscan2
- BEND3 | c.2357C>T p.A786V | Missense Mutation (SNP) | VAF 155/257 reads (60%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.906); catalogued as COSV64681993; called by muse, mutect2, varscan2
- BMP5 | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 155/431 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV63703324; called by muse, mutect2, varscan2
- BNIPL | c.491G>A p.R164Q | Missense Mutation (SNP) | VAF 190/457 reads (42%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs587741752; called by muse, mutect2, varscan2
- BRINP1 | c.2105G>A p.R702Q | Missense Mutation (SNP) | VAF 191/489 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV56297833; called by muse, mutect2
- BRPF3 | c.3199C>T p.P1067S | Missense Mutation (SNP) | VAF 161/468 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1337264436; called by muse, mutect2, varscan2
- C12orf43 | c.751C>T p.P251S | Missense Mutation (SNP) | VAF 102/299 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.067); catalogued as COSV99982422; called by muse, mutect2, varscan2
- C5orf47 | c.131G>A p.G44E | Missense Mutation (SNP) | VAF 181/339 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1394871345; called by muse, mutect2, varscan2
- C6 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 119/296 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.962); catalogued as COSV54720835; called by muse, mutect2, varscan2
- CBL | c.1358C>T p.P453L | Missense Mutation (SNP) | VAF 167/597 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.253); catalogued as rs1262688624; called by muse, mutect2, varscan2
- CCNYL1 | c.619G>A p.E207K (on ENST00000295414 / NM_001330218.2; = p.E137K on NM_152523.2) | Missense Mutation (SNP) | VAF 112/295 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1184968492; called by muse, mutect2, varscan2
- CD163 | c.3260G>A p.G1087E | Missense Mutation (SNP) | VAF 83/235 reads (35%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.895); catalogued as COSV100776184; called by muse, mutect2, varscan2
- CD163L1 | c.3157C>T p.H1053Y | Missense Mutation (SNP) | VAF 184/457 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.031); catalogued as COSV58013913; called by muse, mutect2, varscan2
- CD163L1 | c.1515G>A p.W505* | Nonsense Mutation (SNP) | VAF 161/464 reads (35%) | catalogued as rs1244553053, COSV58024498; called by muse, mutect2, varscan2
- CD1E | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 121/365 reads (33%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs868718790, COSV63769843; called by muse, mutect2, varscan2
- CD33 | c.620G>A p.G207D | Missense Mutation (SNP) | VAF 185/438 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); catalogued as COSV51801343; called by muse, mutect2, varscan2
- CD44 | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 151/408 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs1271862321; called by muse, mutect2, varscan2
- CDH4 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 169/427 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs375893301; called by muse, mutect2, varscan2
- CDH6 | c.1745G>A p.G582E | Missense Mutation (SNP) | VAF 178/498 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as COSV54070491; called by muse, mutect2, varscan2
- CDHR2 | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 12/234 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as rs1295339056; called by muse, mutect2
- CFHR5 | c.1580G>A p.G527E | Missense Mutation (SNP) | VAF 128/328 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1049224798, COSV56829221; called by muse, mutect2, varscan2
- CGB3 | c.436C>T p.P146S | Missense Mutation (SNP) | VAF 102/182 reads (56%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.003); catalogued as rs141896729; called by muse, mutect2, varscan2
- CHGB | c.887G>A p.G296E | Missense Mutation (SNP) | VAF 157/422 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs267606032, COSV66761500; called by muse, mutect2, varscan2
- CHRM2 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 169/763 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.411); catalogued as COSV57776938; called by muse, mutect2, varscan2
- CHRNA4 | c.1489G>A p.D497N | Missense Mutation (SNP) | VAF 231/613 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.102); catalogued as rs1356056029, COSV100937300; called by muse, mutect2
- CLINT1 | c.1585A>G p.S529G | Missense Mutation (SNP) | VAF 131/243 reads (54%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs746861396; called by muse, mutect2, varscan2
- CLMN | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 135/344 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.295); catalogued as COSV54179546; called by muse, mutect2, varscan2
- COG3 | c.737C>T p.P246L | Missense Mutation (SNP) | VAF 64/196 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.83); catalogued as rs1196923328, COSV63072256; called by muse, mutect2, varscan2
- COL1A1 | c.3701C>T p.T1234I | Missense Mutation (SNP) | VAF 227/569 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as rs761711691; called by muse, mutect2, varscan2
- COL1A1 | c.2116G>A p.D706N | Missense Mutation (SNP) | VAF 157/459 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372215246; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL4A3 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 89/288 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.825); catalogued as CM148113; called by muse, mutect2, varscan2
- COL5A1 | c.3757C>T p.P1253S | Missense Mutation (SNP) | VAF 123/347 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs1441643416; called by muse, mutect2, varscan2
- COL5A2 | c.2564G>A p.G855E | Missense Mutation (SNP) | VAF 60/219 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267599128; called by muse, mutect2, varscan2
- COL5A2 | c.2563G>A p.G855R | Missense Mutation (SNP) | VAF 60/212 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1064795616, COSV66413410; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL7A1 | c.4288G>A p.G1430R | Missense Mutation (SNP) | VAF 147/448 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778127992, COSV60393509; called by muse, mutect2, varscan2
- CPA3 | c.937C>T p.P313S | Missense Mutation (SNP) | VAF 89/293 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56043955; called by muse, mutect2, varscan2
- CPZ | c.703G>A p.E235K (on ENST00000360986 / NM_001014447.3; = p.E224K on NM_003652.3) | Missense Mutation (SNP) | VAF 148/368 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.442); catalogued as rs1411209507; called by muse, mutect2, varscan2
- CTBP1 | c.853C>T p.R285C | Missense Mutation (SNP) | VAF 155/454 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV52071859; called by muse, mutect2, varscan2
- CTNND2 | c.1819G>A p.E607K | Missense Mutation (SNP) | VAF 135/329 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.43); catalogued as rs1251135777, COSV58884717, COSV58901519; called by muse, mutect2, varscan2
- CTNND2 | c.1690C>T p.P564S | Missense Mutation (SNP) | VAF 160/445 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs779262763, COSV58872192; called by muse, mutect2, varscan2
- CWH43 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 76/225 reads (34%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs755347963, COSV99893684; called by muse, mutect2, varscan2
- CYP21A2 | c.998C>T p.S333F | Missense Mutation (SNP) | VAF 186/670 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); catalogued as rs1159901869, COSV100926404; called by muse, mutect2, varscan2
- DAP3 | c.965C>T p.A322V | Missense Mutation (SNP) | VAF 115/337 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs753162108; called by muse, mutect2, varscan2
- DDAH2 | c.83G>A p.G28D | Missense Mutation (SNP) | VAF 201/587 reads (34%) | SIFT tolerated (0.65); PolyPhen benign (0.044); catalogued as rs975377875; called by muse, mutect2, varscan2
- DDX17 | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 114/309 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.29); catalogued as rs1168748145; called by muse, mutect2, varscan2
- DDX3X | c.1346C>T p.T449I (on ENST00000399959; = p.T450I on NM_001356.5) | Missense Mutation (SNP) | VAF 116/163 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67863014; called by muse, mutect2, varscan2
- DEFB110 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 98/331 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.094); catalogued as rs145542651, COSV64485051; called by muse, mutect2, varscan2
- DEFB118 | c.329G>A p.R110K | Missense Mutation (SNP) | VAF 136/392 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1286798863; called by muse, mutect2, varscan2
- DENND2D | c.481G>A p.G161S | Missense Mutation (SNP) | VAF 158/422 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs780918814, COSV62959949; called by muse, mutect2, varscan2
- DEUP1 | c.619C>T p.P207S | Missense Mutation (SNP) | VAF 121/370 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.115); catalogued as COSV53211337; called by muse, mutect2, varscan2
- DHH | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 202/482 reads (42%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs1204625645, COSV99908832; called by muse, mutect2, varscan2
- DHX16 | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 212/531 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.068); catalogued as rs761728114, COSV64562906; called by muse, mutect2, varscan2
- DHX34 | c.2050C>T p.R684W | Missense Mutation (SNP) | VAF 109/318 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs550385280; called by muse, mutect2, varscan2
- DNAH5 | c.10369G>A p.E3457K | Missense Mutation (SNP) | VAF 141/395 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.201); catalogued as rs868120629, COSV54242073; called by muse, mutect2, varscan2
- DNAH5 | c.319A>T p.K107* | Nonsense Mutation (SNP) | VAF 123/334 reads (37%) | catalogued as COSV99454101; called by muse, mutect2, varscan2
- DNMT3A | c.2006C>T p.S669F | Missense Mutation (SNP) | VAF 183/441 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53064299, COSV53067349; called by muse, mutect2, varscan2
- DOC2A | c.1199C>T p.A400V | Missense Mutation (SNP) | VAF 106/259 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.011); catalogued as rs201177833; called by muse, mutect2, varscan2
- DPEP2 | c.1040G>A p.G347E | Missense Mutation (SNP) | VAF 142/384 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52055919; called by muse, mutect2, varscan2
- DSCAM | c.5470G>A p.E1824K | Missense Mutation (SNP) | VAF 199/488 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV68023134; called by muse, mutect2, varscan2
- DUSP15 | c.755C>T p.S252L | Missense Mutation (SNP) | VAF 135/399 reads (34%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs1301409817, COSV54066182; called by muse, mutect2, varscan2
- EFCAB6 | c.3898G>A p.V1300M | Missense Mutation (SNP) | VAF 90/283 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs772620252, COSV99412553; called by muse, mutect2, varscan2
- ELP6 | c.308C>T p.P103L | Missense Mutation (SNP) | VAF 122/322 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as rs1157557992; called by muse, mutect2, varscan2
- EML3 | c.470C>T p.S157F | Missense Mutation (SNP) | VAF 112/342 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs776630126; called by muse, mutect2, varscan2
- EML5 | c.1000C>T p.H334Y | Missense Mutation (SNP) | VAF 170/438 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1191803171; called by muse, mutect2, varscan2
- ERC2 | c.2851G>A p.D951N | Missense Mutation (SNP) | VAF 168/469 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.539); catalogued as rs867199823; called by muse, mutect2, varscan2
- ERVV-1 | c.905G>A p.G302E | Missense Mutation (SNP) | VAF 138/506 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.087); catalogued as rs939701171; called by muse, mutect2, varscan2
- ETNK1 | c.445C>T p.H149Y | Missense Mutation (SNP) | VAF 146/369 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56889721; called by muse, mutect2, varscan2
- EXD1 | c.1216G>A p.D406N | Missense Mutation (SNP) | VAF 103/306 reads (34%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV59255171; called by muse, mutect2, varscan2
- EXOC8 | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 174/488 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.118); catalogued as COSV50478226; called by muse, mutect2, varscan2
- EXPH5 | c.4651G>A p.E1551K | Missense Mutation (SNP) | VAF 122/302 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.098); catalogued as rs765714928; called by muse, mutect2, varscan2
- FAAP100 | c.2012C>T p.P671L | Missense Mutation (SNP) | VAF 238/611 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.139); catalogued as rs1167439630; called by muse, mutect2, varscan2
- FAM135B | c.540C>T p.I180= | Splice Region (SNP) | VAF 80/330 reads (24%) | catalogued as rs267601786, COSV50526579; called by muse, mutect2, varscan2
- FAT3 | c.5548C>T p.H1850Y | Missense Mutation (SNP) | VAF 103/318 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.945); catalogued as COSV53093612; called by muse, mutect2, varscan2
- FAT4 | c.9095G>A p.G3032E | Missense Mutation (SNP) | VAF 93/257 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV58709337; called by muse, mutect2, varscan2
- FGF23 | c.447G>A p.M149I | Missense Mutation (SNP) | VAF 122/366 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV52975382; called by muse, mutect2, varscan2
- FKBP15 | c.3316G>A p.D1106N | Missense Mutation (SNP) | VAF 172/464 reads (37%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs916831500; called by muse, mutect2, varscan2
- FREM1 | c.5197C>T p.P1733S | Missense Mutation (SNP) | VAF 73/140 reads (52%) | SIFT tolerated (0.26); PolyPhen benign (0.095); catalogued as rs1427012749; called by muse, mutect2, varscan2
- FSIP2 | c.16555G>A p.E5519K | Missense Mutation (SNP) | VAF 145/411 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1342543979, COSV58078307; called by muse, mutect2, varscan2
- FZD2 | c.1676G>A p.R559Q | Missense Mutation (SNP) | VAF 87/217 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.044); catalogued as rs753511101, COSV59528584; called by muse, mutect2, varscan2
- GABRE | c.1249G>A p.G417R | Missense Mutation (SNP) | VAF 232/317 reads (73%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.543); catalogued as rs1010287857, COSV100944327, COSV64821201; called by muse, mutect2, varscan2
- GAL3ST2 | c.1189G>A p.G397R | Missense Mutation (SNP) | VAF 113/370 reads (31%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.01); catalogued as COSV51949542; called by muse, mutect2, varscan2
- GALNT8 | c.661G>A p.D221N | Missense Mutation (SNP) | VAF 90/232 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104383694; called by muse, mutect2, varscan2
- GBP5 | c.520C>T p.P174S | Missense Mutation (SNP) | VAF 152/416 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs575082350, COSV100600180; called by muse, mutect2, varscan2
- GIPC3 | c.1472C>T p.T491I | Missense Mutation (SNP) | VAF 162/391 reads (41%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.992); catalogued as rs1214293222; called by muse, varscan2
- GLDC | c.395C>T p.S132L | Missense Mutation (SNP) | VAF 127/229 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs386833576, CM061050, CM1510118, COSV58685120; called by muse, mutect2, varscan2
- GLIS1 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 237/614 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.038); catalogued as rs375719960; called by muse, mutect2, varscan2
- GLRA1 | c.806C>T p.S269F | Missense Mutation (SNP) | VAF 136/236 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99199405; called by muse, mutect2, varscan2
- GOLGA6L6 | c.1489G>A p.E497K | Missense Mutation (SNP) | VAF 216/1030 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.908); catalogued as rs1237897184; called by muse, varscan2
- GPATCH8 | c.2590C>T p.R864C | Missense Mutation (SNP) | VAF 186/447 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.306); catalogued as rs754932174; called by muse, mutect2, varscan2
- GPX8 | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 112/332 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.029); catalogued as rs1388007209; called by muse, mutect2, varscan2
- GRHL2 | c.1309G>A p.G437R | Missense Mutation (SNP) | VAF 107/308 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.403); catalogued as COSV52547918; called by muse, mutect2, varscan2
- GRID2 | c.670C>T p.R224* | Nonsense Mutation (SNP) | VAF 154/460 reads (33%) | catalogued as rs200455027, COSV56183410; called by muse, mutect2, varscan2
- GRXCR1 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 90/255 reads (35%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.202); catalogued as COSV67670411; called by muse, mutect2, varscan2
- GYS1 | c.557T>C p.V186A | Missense Mutation (SNP) | VAF 158/435 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV99620491; called by muse, mutect2, varscan2
- HAVCR2 | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 110/207 reads (53%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV57151800; called by muse, mutect2, varscan2
- HCN1 | c.2561G>A p.R854Q | Missense Mutation (SNP) | VAF 174/456 reads (38%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.766); catalogued as rs1060500094, COSV57536554; called by muse, mutect2, varscan2
- HCN1 | c.729G>A p.M243I | Missense Mutation (SNP) | VAF 125/338 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57497756; called by muse, mutect2, varscan2
- HDGFL1 | c.32G>A p.S11N | Missense Mutation (SNP) | VAF 115/334 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.044); catalogued as COSV100014543, COSV57751632; called by muse, mutect2, varscan2
- HNRNPCL1 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 190/540 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.63); catalogued as rs150230498; called by muse, varscan2
- HOXA4 | c.112G>A p.G38R | Missense Mutation (SNP) | VAF 206/538 reads (38%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.67); catalogued as rs746129531, COSV57825070; called by muse, varscan2
- HOXA9 | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 88/247 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as COSV58655739, COSV58656947; called by muse, mutect2, varscan2
- HRNR | c.2228G>A p.G743E | Missense Mutation (SNP) | VAF 159/443 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.776); catalogued as rs267598027; called by muse, mutect2, varscan2
- HS3ST5 | c.863C>T p.A288V | Missense Mutation (SNP) | VAF 121/209 reads (58%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as rs1236849104; called by muse, mutect2, varscan2
- HSD17B3 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 126/357 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.141); catalogued as rs1468885206; called by muse, mutect2, varscan2
- HSPG2 | c.5984G>A p.S1995N | Missense Mutation (SNP) | VAF 118/333 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.754); catalogued as rs1380402967; called by muse, mutect2, varscan2
- HYDIN | c.7669G>A p.E2557K | Missense Mutation (SNP) | VAF 202/539 reads (37%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.994); catalogued as rs267604619, COSV59263830; called by muse, mutect2, varscan2
- IGSF21 | c.1234C>T p.R412C | Missense Mutation (SNP) | VAF 163/408 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1474340067, COSV52132771; called by muse, varscan2
- IL4I1 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 120/332 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.881); catalogued as rs778722296, COSV100352197; called by muse, mutect2, varscan2
- ILDR1 | c.1313C>T p.P438L (on ENST00000344209 / NM_001199799.2; = p.P394L on NM_175924.4) | Missense Mutation (SNP) | VAF 203/521 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV56553119; called by muse, mutect2, varscan2
- ILDR1 | c.1312C>T p.P438S (on ENST00000344209 / NM_001199799.2; = p.P394S on NM_175924.4) | Missense Mutation (SNP) | VAF 202/519 reads (39%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs554966703, COSV56546867; called by muse, mutect2, varscan2
- IQSEC1 | c.436C>T p.R146C | Missense Mutation (SNP) | VAF 191/488 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56229085; called by muse, mutect2, varscan2
- IRGC | c.1043C>T p.S348F | Missense Mutation (SNP) | VAF 180/516 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.314); catalogued as rs764738059, COSV54983200, COSV54983936; called by muse, mutect2, varscan2
- ITM2A | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 150/196 reads (77%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64810927; called by muse, mutect2, varscan2
- IVL | c.37C>T p.P13S | Missense Mutation (SNP) | VAF 115/304 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.581); catalogued as rs201971901; called by muse, mutect2, varscan2
- KANK4 | c.2819G>A p.G940D | Missense Mutation (SNP) | VAF 196/568 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as rs201058418; called by muse, mutect2
- KBTBD3 | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 86/250 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs369236490; called by muse, mutect2, varscan2
- KCNA5 | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 196/458 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV52905790; called by muse, mutect2, varscan2
- KCNH7 | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 126/334 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as rs779754574; called by muse, mutect2, varscan2
- KCNJ11 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 207/564 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs145429555; called by muse, mutect2, varscan2
- KCNQ5 | c.1733G>A p.G578E | Missense Mutation (SNP) | VAF 90/162 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs866112375, COSV100572826; called by muse, mutect2, varscan2
- KCNV1 | c.1114C>T p.P372S | Missense Mutation (SNP) | VAF 150/363 reads (41%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.998); catalogued as rs865900317, COSV52085529; called by muse, mutect2, varscan2
- KIAA1217 | c.5681C>T p.S1894F | Missense Mutation (SNP) | VAF 145/401 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); catalogued as COSV56819213; called by muse, mutect2, varscan2
- KIR2DL3 | c.328C>T p.Q110* | Nonsense Mutation (SNP) | VAF 68/287 reads (24%) | catalogued as rs754862541, COSV60897196; called by muse, mutect2, varscan2
- KIR3DL1 | c.1120G>A p.D374N | Missense Mutation (SNP) | VAF 92/323 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.062); catalogued as rs765254208; called by muse, mutect2, varscan2
- KIRREL3 | c.118C>T p.R40W | Missense Mutation (SNP) | VAF 150/554 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.973); catalogued as rs119462978, CM086843; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LELP1 | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 161/425 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV64202405; called by muse, mutect2, varscan2
- LOXHD1 | c.6180G>A p.R2060= (on ENST00000642948; = p.R1998= on NM_144612.7) | Splice Region (SNP) | VAF 71/193 reads (37%) | catalogued as COSV56061771; called by muse, mutect2, varscan2
- LRGUK | c.2125G>A p.E709K | Missense Mutation (SNP) | VAF 101/487 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0.118); catalogued as rs1312577313; called by muse, mutect2, varscan2
- LRIT2 | c.858G>A p.W286* | Nonsense Mutation (SNP) | VAF 111/203 reads (55%) | catalogued as rs866647312, COSV60566106; called by muse, mutect2, varscan2
- LRP1B | c.11347C>T p.R3783* | Nonsense Mutation (SNP) | VAF 161/455 reads (35%) | catalogued as rs755519211, COSV101260873, COSV67219306; called by muse, mutect2, varscan2
- LRP1B | c.9191G>A p.R3064Q | Missense Mutation (SNP) | VAF 125/322 reads (39%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.834); catalogued as rs1196321476, COSV67206893; called by muse, mutect2, varscan2
- LRRC8B | c.920C>T p.S307F | Missense Mutation (SNP) | VAF 170/425 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as COSV58376038; called by muse, mutect2, varscan2
- LRRIQ3 | c.1483G>A p.E495K | Missense Mutation (SNP) | VAF 98/286 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV63043660; called by muse, mutect2, varscan2
- LRRN3 | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 145/721 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs145461505, COSV57821496; called by muse, mutect2, varscan2
- LTBP1 | c.845C>T p.P282L | Missense Mutation (SNP) | VAF 122/320 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs760702803; called by muse, mutect2, varscan2
- LTBP1 | c.5015G>A p.R1672Q (on ENST00000404816 / NM_206943.4; = p.R1346Q on NM_000627.4) | Missense Mutation (SNP) | VAF 104/335 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs145029619; called by muse, mutect2, varscan2
- LYZL2 | c.288G>A p.M96I (on ENST00000375318; = p.M50I on NM_183058.3) | Missense Mutation (SNP) | VAF 105/335 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.137); catalogued as rs1318562257; called by muse, mutect2, varscan2
- MAGEA10 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 249/320 reads (78%) | SIFT tolerated (0.14); PolyPhen benign (0.115); catalogued as COSV54885824; called by muse, mutect2, varscan2
- MAGEB6 | c.1054C>T p.P352S | Missense Mutation (SNP) | VAF 183/272 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1413833390, COSV66872246; called by muse, mutect2, varscan2
- MALRD1 | c.2885G>A p.R962Q | Missense Mutation (SNP) | VAF 149/370 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as rs140205728; called by muse, mutect2, varscan2
- MAN2B1 | c.1658C>T p.P553L | Missense Mutation (SNP) | VAF 112/272 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.253); catalogued as rs868050025; called by muse, mutect2, varscan2
- METTL25 | c.1264G>A p.E422K | Missense Mutation (SNP) | VAF 125/315 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as COSV50262948; called by muse, mutect2, varscan2
- MME | c.1858C>T p.Q620* | Nonsense Mutation (SNP) | VAF 146/393 reads (37%) | catalogued as COSV100852509; called by muse, mutect2, varscan2
- MMP26 | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 113/301 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.023); catalogued as COSV56171595; called by muse, mutect2, varscan2
- MRC1 | c.3982G>A p.E1328K | Missense Mutation (SNP) | VAF 196/544 reads (36%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.673); catalogued as COSV53469831; called by muse, mutect2
- MUC12 | c.1292C>T p.S431L (on ENST00000379442; = p.S288L on NM_001164462.1) | Missense Mutation (SNP) | VAF 600/914 reads (66%) | SIFT deleterious (0.01); PolyPhen benign (0.35); catalogued as rs1198721514, COSV65186899; called by muse, mutect2
- MUC16 | c.43228G>A p.E14410K | Missense Mutation (SNP) | VAF 139/399 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as COSV66694294; called by muse, mutect2, varscan2
- MUC16 | c.35605C>T p.L11869F | Missense Mutation (SNP) | VAF 154/392 reads (39%) | SIFT tolerated, low confidence (0.69); PolyPhen possibly damaging (0.534); catalogued as COSV67446830; called by muse, mutect2, varscan2
- MUC16 | c.19214C>T p.S6405F | Missense Mutation (SNP) | VAF 159/415 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.053); catalogued as COSV67476540, COSV67488045; called by muse, mutect2, varscan2
- MUC4 | c.6596C>T p.S2199F | Missense Mutation (SNP) | VAF 237/1062 reads (22%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.496); catalogued as rs1293183054, COSV100640141; called by muse, mutect2, varscan2
- MUC4 | c.1556G>A p.G519E | Missense Mutation (SNP) | VAF 269/714 reads (38%) | SIFT tolerated, low confidence (0.95); PolyPhen probably damaging (0.934); catalogued as COSV62154451; called by muse, mutect2, varscan2
- MUCL1 | c.53C>T p.S18F | Missense Mutation (SNP) | VAF 117/293 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.723); catalogued as rs760140523, COSV58192561; called by muse, mutect2
- MUSK | c.860A>G p.K287R | Missense Mutation (SNP) | VAF 143/376 reads (38%) | SIFT tolerated (0.48); PolyPhen benign (0.174); catalogued as COSV51883473; called by muse, mutect2, varscan2
- MYH15 | c.4453G>A p.E1485K | Missense Mutation (SNP) | VAF 124/326 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV56316451; called by muse, mutect2, varscan2
- MYH4 | c.2335G>A p.E779K | Missense Mutation (SNP) | VAF 148/250 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs776140827, COSV55116809; called by muse, mutect2, varscan2
- MYH4 | c.1095G>A p.M365I | Missense Mutation (SNP) | VAF 129/211 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.167); catalogued as COSV55117180; called by muse, mutect2, varscan2
- MYH8 | c.3586C>T p.R1196W | Missense Mutation (SNP) | VAF 103/173 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765916450, COSV67966297; called by muse, mutect2, varscan2
- MYO18B | c.7625C>T p.S2542F | Missense Mutation (SNP) | VAF 144/398 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs931383672; called by muse, mutect2, varscan2
- MYO5B | c.2491G>A p.A831T | Missense Mutation (SNP) | VAF 182/505 reads (36%) | SIFT tolerated (0.58); PolyPhen benign (0.118); catalogued as rs376725688; called by muse, mutect2, varscan2
- MYOCD | c.1599G>A p.W533* | Nonsense Mutation (SNP) | VAF 168/261 reads (64%) | catalogued as COSV58499691; called by muse, mutect2, varscan2
- MYOM3 | c.418C>T p.Q140* | Nonsense Mutation (SNP) | VAF 109/358 reads (30%) | catalogued as rs1420993746; called by muse, mutect2, varscan2
- NAGA | c.308C>T p.P103L | Missense Mutation (SNP) | VAF 122/373 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.16); catalogued as rs766999974; called by muse, varscan2
- NEB | c.2609C>T p.S870F | Missense Mutation (SNP) | VAF 131/358 reads (37%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.997); catalogued as rs896068588, COSV51113140; called by muse, mutect2, varscan2
- NEFH | c.2428C>T p.P810S | Missense Mutation (SNP) | VAF 169/468 reads (36%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as rs770240562, COSV100151530; called by muse, mutect2, varscan2
- NHSL2 | c.470C>T p.A157V (on ENST00000510661; = p.A523V on NM_001013627.2) | Missense Mutation (SNP) | VAF 108/145 reads (74%) | SIFT tolerated (0.05); PolyPhen benign (0.152); catalogued as rs1342069039, COSV65454342; called by muse, mutect2, varscan2
- NID2 | c.1717C>T p.P573S | Missense Mutation (SNP) | VAF 137/407 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1342887997; called by muse, mutect2, varscan2
- NIPAL1 | c.889G>A p.A297T | Missense Mutation (SNP) | VAF 138/398 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs766220617; called by muse, mutect2, varscan2
- NLRP7 | c.368G>A p.W123* | Nonsense Mutation (SNP) | VAF 152/351 reads (43%) | catalogued as COSV60180642; called by muse, mutect2, varscan2
- NMUR1 | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 196/572 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100531764; called by muse, mutect2, varscan2
- NPAP1 | c.1775C>T p.S592F | Missense Mutation (SNP) | VAF 136/346 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV61507055; called by muse, mutect2, varscan2
- NPAS1 | c.525G>A p.V175= | Splice Region (SNP) | VAF 104/305 reads (34%) | catalogued as rs767993138, COSV71384006; called by muse, mutect2, varscan2
- NPAS1 | c.1018C>T p.Q340* | Nonsense Mutation (SNP) | VAF 196/520 reads (38%) | catalogued as rs1229380143; called by muse, mutect2
- NPAS3 | c.194G>A p.G65E (on ENST00000356141 / NM_001164749.2; = p.G35E on NM_022123.3) | Missense Mutation (SNP) | VAF 157/374 reads (42%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.953); catalogued as COSV100390282; called by muse, mutect2, varscan2
- NPHP1 | c.329A>T p.E110V | Missense Mutation (SNP) | VAF 177/415 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as COSV100338540; called by muse, mutect2, varscan2
- NPIPB15 | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 44/381 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.036); catalogued as rs375786148; called by muse, mutect2, varscan2
- OGDHL | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 138/220 reads (63%) | SIFT tolerated (0.11); PolyPhen benign (0.086); catalogued as rs771174825, COSV65102591; called by muse, mutect2, varscan2
- OPRPN | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 76/228 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); catalogued as COSV68192596; called by muse, mutect2, varscan2
- OR10J3 | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 163/430 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV59954068; called by muse, mutect2, varscan2
- OR10P1 | c.46G>A p.G16R | Missense Mutation (SNP) | VAF 105/306 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as rs768263813; called by muse, varscan2
- OR10X1 | c.743A>G p.E248G | Missense Mutation (SNP) | VAF 122/359 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); catalogued as rs1358024013; called by muse, mutect2, varscan2
- OR1A1 | c.799C>G p.L267V | Missense Mutation (SNP) | VAF 128/206 reads (62%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.801); catalogued as rs770470632, COSV100410815; called by muse, mutect2, varscan2
- OR1L3 | c.496C>T p.L166F | Missense Mutation (SNP) | VAF 149/384 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100506197, COSV59170024; called by muse, mutect2, varscan2
- OR2H1 | c.292C>A p.Q98K | Missense Mutation (SNP) | VAF 268/705 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV65810276; called by muse, mutect2, varscan2
- OR4C11 | c.221C>T p.S74F | Missense Mutation (SNP) | VAF 144/194 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV56352210; called by muse, mutect2, varscan2
- OR4K2 | c.17A>G p.K6R | Missense Mutation (SNP) | VAF 55/293 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.028); catalogued as rs1405663306, COSV53848327, COSV53851350; called by muse, mutect2, varscan2
- OR4X1 | c.835C>T p.L279F | Missense Mutation (SNP) | VAF 103/319 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.142); catalogued as rs773901923; called by muse, mutect2, varscan2
- OR51E1 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 157/436 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs142449769, COSV67810348; called by muse, mutect2, varscan2
- OR51Q1 | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 100/279 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as rs372480233, COSV56180547; called by muse, mutect2
- OR52M1 | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 126/456 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as rs199531820; called by muse, mutect2
- OR5AS1 | c.467C>T p.S156L | Missense Mutation (SNP) | VAF 156/398 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.783); catalogued as rs867857564, COSV57982587; called by muse, mutect2, varscan2
- OR5H1 | c.899C>T p.S300L | Missense Mutation (SNP) | VAF 81/237 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV63402245, COSV63402524, COSV63403532; called by muse, mutect2, varscan2
- OR5T2 | c.239G>A p.G80E | Missense Mutation (SNP) | VAF 311/415 reads (75%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as COSV57587719; called by muse, varscan2
- OR6F1 | c.920G>A p.G307E | Missense Mutation (SNP) | VAF 66/181 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.037); catalogued as rs866322456, COSV57469416; called by muse, mutect2, varscan2
- OR6F1 | c.919G>A p.G307R | Missense Mutation (SNP) | VAF 66/183 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV57469171; called by muse, mutect2, varscan2
- OR7D2 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 167/442 reads (38%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.007); catalogued as rs1347866764, COSV60140672; called by muse, mutect2, varscan2
- OSBP2 | c.1964G>A p.G655E | Missense Mutation (SNP) | VAF 105/248 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1330917217; called by muse, mutect2, varscan2
- OTOGL | c.6998G>A p.G2333E (on ENST00000547103; = p.G2324E on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 98/275 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1260290150, COSV54018199; called by muse, mutect2, varscan2
- PACC1 | c.277C>T p.R93C | Missense Mutation (SNP) | VAF 148/390 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs754623496, COSV54787341; called by muse, mutect2, varscan2
- PAK5 | c.1786G>A p.E596K | Missense Mutation (SNP) | VAF 122/322 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); catalogued as COSV62034115; called by muse, mutect2, varscan2
- PAK5 | c.346G>A p.G116S | Missense Mutation (SNP) | VAF 146/427 reads (34%) | SIFT tolerated (0.7); PolyPhen benign (0.111); catalogued as rs757167550, COSV100781635, COSV62024463; called by muse, mutect2, varscan2
- PCDH15 | c.619C>T p.P207S | Missense Mutation (SNP) | VAF 107/176 reads (61%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.456); catalogued as COSV57275583; called by muse, mutect2, varscan2
- PCDHA3 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 96/168 reads (57%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.007); catalogued as rs782260016, COSV65365377, COSV65367658; called by muse, mutect2, varscan2
- PCDHA3 | c.1867C>T p.R623C | Missense Mutation (SNP) | VAF 122/217 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.16); catalogued as COSV63539394; called by muse, mutect2, varscan2
- PCDHA5 | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 82/145 reads (57%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.021); catalogued as rs267600389, COSV65349351; called by muse, mutect2, varscan2
- PCDHA9 | c.1796C>T p.A599V | Missense Mutation (SNP) | VAF 12/344 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.159); catalogued as rs782425750; called by muse, mutect2
- PCDHAC1 | c.2342G>A p.R781Q | Missense Mutation (SNP) | VAF 195/321 reads (61%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as rs781843995, COSV53836291; called by muse, mutect2, varscan2
- PCDHB13 | c.392C>T p.S131F | Missense Mutation (SNP) | VAF 110/201 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.079); catalogued as COSV53401225; called by muse, mutect2, varscan2
- PCDHB4 | c.621C>A p.F207L | Missense Mutation (SNP) | VAF 206/334 reads (62%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV52024561; called by muse, mutect2, varscan2
- PCDHGA4 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 135/220 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV54060225; called by muse, mutect2, varscan2
- PCDHGB2 | c.1024G>A p.D342N | Missense Mutation (SNP) | VAF 132/250 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776154088, COSV53942072; called by muse, mutect2, varscan2
- PCLO | c.5755G>A p.E1919K | Missense Mutation (SNP) | VAF 183/753 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61655590; called by muse, mutect2, varscan2
- PDGFRA | c.2486G>A p.G829E | Missense Mutation (SNP) | VAF 138/376 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV57268333, COSV99955745; called by muse, mutect2, varscan2
- PDILT | c.662G>A p.S221N | Missense Mutation (SNP) | VAF 101/298 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.955); catalogued as COSV100199630; called by muse, mutect2, varscan2
- PHC1 | c.842C>T p.P281L | Missense Mutation (SNP) | VAF 30/148 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.259); catalogued as rs1265567640; called by muse, mutect2, varscan2
- PHRF1 | c.2446C>T p.L816F (on ENST00000264555 / NM_001286581.2; = p.L815F on NM_020901.4) | Missense Mutation (SNP) | VAF 200/516 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.092); catalogued as rs754994881; called by muse, mutect2, varscan2
- PIKFYVE | c.412C>T p.L138F | Missense Mutation (SNP) | VAF 88/280 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV52249845; called by muse, mutect2, varscan2
- PIP4K2A | c.935C>T p.T312I | Missense Mutation (SNP) | VAF 142/414 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs773012225, COSV60539782; called by muse, varscan2
- PKHD1L1 | c.8143G>A p.E2715K | Missense Mutation (SNP) | VAF 145/412 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.495); catalogued as COSV65737981; called by muse, mutect2, varscan2
- PLB1 | c.4174-1G>A p.X1392_splice | Splice Site (SNP) | VAF 96/259 reads (37%) | catalogued as rs778192063; called by muse, mutect2, varscan2
- PLB1 | c.4174G>A p.E1392K | Missense Mutation (SNP) | VAF 97/262 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.129); catalogued as rs141768418; called by muse, mutect2, varscan2
- PLEC | c.2428A>G p.K810E (on ENST00000322810 / NM_201380.4; = p.K700E on NM_000445.5) | Missense Mutation (SNP) | VAF 155/583 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as rs1407260713; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLEKHG3 | c.1741C>T p.R581W (on ENST00000394691; = p.R637W on NM_001308147.2) | Missense Mutation (SNP) | VAF 149/456 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746230543; called by muse, mutect2, varscan2
- PLEKHG3 | c.2140C>T p.P714S (on ENST00000394691; = p.P770S on NM_001308147.2) | Missense Mutation (SNP) | VAF 157/452 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.313); catalogued as rs1566717935, COSV55982585; called by muse, mutect2, varscan2
- PLOD3 | c.615G>A p.R205= | Splice Region (SNP) | VAF 104/428 reads (24%) | catalogued as rs757271400; called by muse, mutect2, varscan2
- POGLUT3 | c.355C>T p.L119F | Missense Mutation (SNP) | VAF 141/421 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.048); catalogued as rs879240444; called by muse, mutect2, varscan2
- POTEA | c.1085G>A p.G362D (on ENST00000519951 / NM_001005365.2; = p.G316D on NM_001002920.1) | Missense Mutation (SNP) | VAF 87/245 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.132); catalogued as rs1349054714; called by muse, mutect2, varscan2
- POTEG | c.72G>A p.M24I | Missense Mutation (SNP) | VAF 134/986 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); catalogued as rs1405514751; called by muse, varscan2
- POTEJ | c.2935G>A p.E979K | Missense Mutation (SNP) | VAF 57/472 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.895); catalogued as rs1452103294; called by muse, mutect2, varscan2
- PPARGC1A | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 135/359 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as rs751487886, COSV53529383; called by muse, mutect2, varscan2
- PRKCB | c.1076C>T p.S359L | Missense Mutation (SNP) | VAF 83/249 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as COSV57780160; called by muse, mutect2, varscan2
- PRL | c.204C>T p.F68= | Splice Region (SNP) | VAF 71/192 reads (37%) | catalogued as rs1328141274, COSV60591377; called by muse, mutect2, varscan2
- PRLR | c.353A>T p.Y118F | Missense Mutation (SNP) | VAF 107/286 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.058); catalogued as rs771815652; called by muse, mutect2, varscan2
- PRMT3 | c.608C>T p.S203L | Missense Mutation (SNP) | VAF 163/441 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs142076035; called by muse, mutect2, varscan2
- PSG6 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 172/523 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.17); catalogued as COSV51830662, COSV99413742; called by muse, mutect2, varscan2
- PSMB9 | c.616C>T p.R206* | Nonsense Mutation (SNP) | VAF 167/453 reads (37%) | catalogued as rs1485245049; called by muse, mutect2, varscan2
- PTGES3L-AARSD1 | c.200A>G p.D67G (on ENST00000421990 / NM_001136042.2; = p.D49G on NM_025267.3) | Missense Mutation (SNP) | VAF 102/320 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.266); catalogued as rs1474237810; called by muse, mutect2, varscan2
- PTPRK | c.3093G>A p.R1031= (on ENST00000368215 / NM_001291984.2; = p.R1032= on NM_002844.4) | Splice Region (SNP) | VAF 75/143 reads (52%) | catalogued as rs1437722344; called by muse, mutect2, varscan2
- PTPRN2 | c.1573G>A p.E525K | Missense Mutation (SNP) | VAF 504/816 reads (62%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV67039045; called by muse, mutect2
- RANBP2 | c.9227C>T p.P3076L | Missense Mutation (SNP) | VAF 161/395 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.716); catalogued as COSV99312109; called by muse, mutect2, varscan2
- RFX5 | c.1214G>A p.G405E | Missense Mutation (SNP) | VAF 172/405 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.448); catalogued as rs892104210; called by muse, mutect2, varscan2
- RIMS2 | c.1625G>A p.G542E (on ENST00000666250 / NM_001348490.2; = p.G350E on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 90/237 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748639640; called by muse, mutect2, varscan2
- ROBO1 | c.1372C>T p.R458* | Nonsense Mutation (SNP) | VAF 123/309 reads (40%) | catalogued as rs763061726, COSV101458502, COSV71395871; called by muse, mutect2, varscan2
- RP1L1 | c.764C>T p.P255L | Missense Mutation (SNP) | VAF 135/219 reads (62%) | SIFT tolerated (0.09); PolyPhen benign (0.057); catalogued as COSV66761009; called by muse, mutect2, varscan2
- RPGRIP1 | c.3058G>A p.E1020K | Missense Mutation (SNP) | VAF 107/279 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.388); catalogued as COSV52843800; called by muse, mutect2, varscan2
- RTL5 | c.242G>A p.G81E | Missense Mutation (SNP) | VAF 217/278 reads (78%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV101030120; called by muse, mutect2, varscan2
- RTN1 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 157/414 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV50718436; called by muse, mutect2, varscan2
- SALL1 | c.1169C>T p.P390L | Missense Mutation (SNP) | VAF 152/464 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.36); catalogued as COSV51757872; called by muse, mutect2, varscan2
- SCARA5 | c.1346G>A p.G449E | Missense Mutation (SNP) | VAF 120/198 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1051572545, COSV61571333, COSV61572017; called by muse, mutect2, varscan2
- SCN9A | c.3587G>A p.S1196N (on ENST00000303354; = p.S1185N on NM_002977.3) | Missense Mutation (SNP) | VAF 126/402 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.245); catalogued as rs1249809900; called by muse, mutect2, varscan2
- SCN9A | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 108/323 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202083986, COSV57599428; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SDK1 | c.5518G>A p.E1840K | Missense Mutation (SNP) | VAF 133/388 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.903); catalogued as rs760624642, COSV101269526, COSV67389663; called by muse, mutect2, varscan2
- SDK2 | c.6482C>T p.S2161F | Missense Mutation (SNP) | VAF 152/426 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs754491697; called by muse, mutect2, varscan2
- SEMA3D | c.805C>T p.Q269* | Nonsense Mutation (SNP) | VAF 83/463 reads (18%) | catalogued as COSV52390423; called by muse, mutect2, varscan2
- SEMA3F | c.2176C>T p.P726S | Missense Mutation (SNP) | VAF 184/483 reads (38%) | SIFT tolerated (0.66); PolyPhen benign (0.079); catalogued as COSV50028271; called by muse, mutect2, varscan2
- SEPTIN4 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 171/462 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1258926912, COSV58729227; called by muse, mutect2, varscan2
- SGMS2 | c.181C>G p.Q61E | Missense Mutation (SNP) | VAF 152/390 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0.098); catalogued as rs1158952966; called by muse, mutect2, varscan2
- SLC15A2 | c.1358C>T p.S453F | Missense Mutation (SNP) | VAF 124/344 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.033); catalogued as COSV55200857; called by muse, mutect2, varscan2
- SLC15A4 | c.1340C>T p.A447V | Missense Mutation (SNP) | VAF 169/454 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV57160900; called by muse, mutect2, varscan2
- SLC22A12 | c.1649C>T p.S550F | Missense Mutation (SNP) | VAF 89/322 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV55453707; called by muse, mutect2, varscan2
- SLC22A16 | c.743C>T p.S248F | Missense Mutation (SNP) | VAF 179/295 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as COSV57933166; called by muse, mutect2, varscan2
- SLC2A6 | c.788C>T p.S263L | Missense Mutation (SNP) | VAF 122/310 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.839); catalogued as rs587620470; called by muse, mutect2, varscan2
- SLC30A8 | c.1061C>T p.P354L | Missense Mutation (SNP) | VAF 341/614 reads (56%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs1467735700, COSV69974487; called by muse, mutect2, varscan2
- SLC37A2 | c.514T>C p.F172L | Missense Mutation (SNP) | VAF 146/494 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as rs1015742810; called by muse, mutect2
- SLC4A10 | c.2011G>A p.E671K (on ENST00000446997 / NM_001354461.2; = p.E641K on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 89/287 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.271); catalogued as COSV55780193; called by muse, mutect2, varscan2
- SLTM | c.1954C>T p.R652C | Missense Mutation (SNP) | VAF 152/376 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as COSV51054183, COSV51055699; called by muse, varscan2
- SNAP47 | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 152/468 reads (32%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as rs1428859642; called by muse, mutect2, varscan2
- SNX31 | c.1042C>T p.Q348* | Nonsense Mutation (SNP) | VAF 114/284 reads (40%) | catalogued as COSV61261677, COSV61265490; called by muse, mutect2, varscan2
- SOWAHB | c.1337G>A p.R446Q | Missense Mutation (SNP) | VAF 148/421 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs760519099; called by muse, mutect2, varscan2
- SOX30 | c.1699G>A p.E567K | Missense Mutation (SNP) | VAF 198/337 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs112851243; called by muse, mutect2, varscan2
- SPATA22 | c.904C>T p.R302C | Missense Mutation (SNP) | VAF 73/123 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as rs200436007, COSV52152180; called by muse, mutect2, varscan2
- SPECC1L | c.1732C>T p.R578C | Missense Mutation (SNP) | VAF 140/376 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs760771508; called by muse, mutect2, varscan2
- SPINT3 | c.23C>T p.S8L | Missense Mutation (SNP) | VAF 126/345 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as rs985823373; called by muse, mutect2, varscan2
- SPN | c.1180G>A p.G394R | Missense Mutation (SNP) | VAF 158/446 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as rs1436890822; called by muse, mutect2, varscan2
- SPRED3 | c.343C>T p.R115* | Nonsense Mutation (SNP) | VAF 118/334 reads (35%) | catalogued as COSV100612621; called by muse, mutect2, varscan2
- SRD5A2 | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 117/336 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.985); catalogued as rs749199514, COSV51871095, COSV99252566; called by muse, mutect2, varscan2
- SSTR4 | c.379G>A p.G127S | Missense Mutation (SNP) | VAF 156/448 reads (35%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.466); catalogued as rs775936596, COSV54797651; called by muse, mutect2, varscan2
- ST6GALNAC1 | c.497G>A p.G166E | Missense Mutation (SNP) | VAF 153/433 reads (35%) | PolyPhen possibly damaging (0.87); catalogued as rs1441384646, COSV50080677; called by muse, mutect2, varscan2
- STAB2 | c.3104C>T p.S1035F | Missense Mutation (SNP) | VAF 188/506 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778993122, COSV66333512; called by muse, mutect2, varscan2
- STARD13 | c.3299C>T p.S1100F (on ENST00000336934 / NM_001243476.3; = p.S982F on NM_052851.3) | Missense Mutation (SNP) | VAF 146/404 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV55229170, COSV55232831; called by muse, mutect2, varscan2
- STEAP4 | c.833G>A p.R278Q | Missense Mutation (SNP) | VAF 179/764 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.527); catalogued as rs749073411, COSV57329325, COSV57331130; called by muse, mutect2, varscan2
- STOX2 | c.2059G>A p.E687K | Missense Mutation (SNP) | VAF 147/387 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.15); catalogued as rs755114314; called by muse, mutect2, varscan2
- STYXL2 | c.2156C>T p.S719F | Missense Mutation (SNP) | VAF 153/456 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV99610024; called by muse, mutect2, varscan2
- SULT1E1 | c.871C>T p.R291* | Nonsense Mutation (SNP) | VAF 64/170 reads (38%) | catalogued as rs202067669, COSV56947970; called by muse, mutect2, varscan2
- SULT2A1 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 146/416 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs763687131, COSV55764410; called by muse, mutect2, varscan2
- TANC1 | c.5561G>A p.R1854Q | Missense Mutation (SNP) | VAF 134/326 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs182648493; called by muse, mutect2, varscan2
- TCP11 | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 115/274 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs909615555, COSV55136381; called by muse, mutect2, varscan2
- TDRD5 | c.2455G>A p.E819K | Missense Mutation (SNP) | VAF 137/378 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.368); catalogued as rs867054398; called by muse, mutect2
- TEK | c.3344G>A p.G1115E | Missense Mutation (SNP) | VAF 133/224 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1364520799, COSV66231989; called by muse, mutect2, varscan2
- TFDP1 | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 99/293 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.15); catalogued as COSV64740248; called by muse, mutect2, varscan2
- THSD4 | c.2896G>A p.D966N | Missense Mutation (SNP) | VAF 76/223 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.494); catalogued as rs865846564; called by muse, mutect2, varscan2
- TIE1 | c.1052C>T p.P351L | Missense Mutation (SNP) | VAF 102/267 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV100992234; called by muse, mutect2, varscan2
- TIMM44 | c.925G>A p.A309T | Missense Mutation (SNP) | VAF 149/419 reads (36%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1032712005; called by muse, mutect2, varscan2
- TJP2 | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 171/454 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs141496493; called by muse, mutect2, varscan2
- TLE3 | c.802C>T p.P268S | Missense Mutation (SNP) | VAF 172/452 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.081); catalogued as COSV58167892; called by muse, mutect2, varscan2
- TLE4 | c.1609C>T p.R537C | Missense Mutation (SNP) | VAF 68/200 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54627080; called by muse, mutect2, varscan2
- TLL1 | c.1888A>C p.T630P | Missense Mutation (SNP) | VAF 126/331 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as COSV50284389; called by muse, mutect2, varscan2
- TMEM106A | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 158/422 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV57831635; called by muse, mutect2, varscan2
- TMEM132C | c.1663C>T p.R555C | Missense Mutation (SNP) | VAF 129/327 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs757837336, COSV59428813; called by muse, mutect2, varscan2
- TMEM196 | c.419G>A p.R140K | Missense Mutation (SNP) | VAF 112/335 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV68256875; called by muse, mutect2, varscan2
- TNC | c.4624C>T p.P1542S | Missense Mutation (SNP) | VAF 153/357 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.356); catalogued as COSV60783248; called by muse, mutect2, varscan2
- TNNI3K | c.1984G>A p.E662K | Missense Mutation (SNP) | VAF 110/317 reads (35%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.93); catalogued as rs747300364, COSV58547042; called by muse, mutect2, varscan2
- TNPO3 | c.2597C>T p.P866L | Missense Mutation (SNP) | VAF 288/459 reads (63%) | SIFT tolerated (0.23); PolyPhen benign (0.023); catalogued as rs199600419, COSV55289535; called by muse, mutect2, varscan2
- TNRC18 | c.3695C>T p.S1232F | Missense Mutation (SNP) | VAF 220/527 reads (42%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.086); catalogued as rs747760066, COSV68166541; called by muse, mutect2, varscan2
- TPTE | c.1571G>A p.R524Q (on ENST00000618007 / NM_199261.4; = p.R506Q on NM_199259.4) | Missense Mutation (SNP) | VAF 123/637 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.113); catalogued as rs749565759; called by muse, varscan2
- TRANK1 | c.2356G>A p.D786N | Missense Mutation (SNP) | VAF 161/384 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.06); catalogued as rs772268133, COSV57160216; called by muse, mutect2, varscan2
- TRAT1 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 126/305 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55467290; called by muse, mutect2, varscan2
- TRAV9-1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 143/353 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1312066427; called by muse, mutect2, varscan2
- TRIM39-RPP21 | c.1282C>T p.Q428* | Nonsense Mutation (SNP) | VAF 114/341 reads (33%) | catalogued as rs1021829204; called by muse, mutect2, varscan2
- TRIM55 | c.469C>T p.Q157* | Nonsense Mutation (SNP) | VAF 134/347 reads (39%) | catalogued as rs370883188; called by muse, mutect2, varscan2
- TRPA1 | c.3169C>T p.L1057F | Missense Mutation (SNP) | VAF 92/264 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV51565044, COSV51573221; called by muse, mutect2, varscan2
- TSPAN8 | c.201G>A p.M67I | Missense Mutation (SNP) | VAF 179/469 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as COSV56081104; called by muse, mutect2, varscan2
- TTC36 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 118/362 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.251); catalogued as rs966997374; called by muse, mutect2, varscan2
- TTN | c.20753G>A p.R6918K (on ENST00000591111; = p.R5991K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 101/254 reads (40%) | PolyPhen benign (0); catalogued as COSV60030775; called by muse, mutect2, varscan2
- TTN | c.9166C>T p.R3056C (on ENST00000591111; = p.R3010C on NM_003319.4) | Missense Mutation (SNP) | VAF 100/222 reads (45%) | PolyPhen probably damaging (0.998); catalogued as rs377207838; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUT4 | c.4676C>T p.S1559F | Missense Mutation (SNP) | VAF 124/319 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.051); catalogued as COSV57117966; called by muse, mutect2, varscan2
- TUT7 | c.4088G>A p.R1363K | Missense Mutation (SNP) | VAF 93/253 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.115); catalogued as rs1468242400; called by muse, mutect2, varscan2
- TXNDC2 | c.737C>T p.T246I (on ENST00000306084 / NM_001098529.2; = p.T179I on NM_032243.6) | Missense Mutation (SNP) | VAF 210/569 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.049); catalogued as COSV60156008; called by muse, mutect2, varscan2
- TYK2 | c.2653C>T p.P885S | Missense Mutation (SNP) | VAF 130/349 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as COSV53384554; called by muse, mutect2, varscan2
- U2AF2 | c.691G>A p.D231N | Missense Mutation (SNP) | VAF 149/444 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1360988399, COSV58272636; called by muse, mutect2, varscan2
- UBN1 | c.2818C>T p.P940S | Missense Mutation (SNP) | VAF 163/449 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as COSV52168644; called by muse, mutect2, varscan2
- UNC79 | c.2557G>A p.E853K (on ENST00000393151 / NM_001346218.2; = p.E676K on NM_020818.5) | Missense Mutation (SNP) | VAF 171/537 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs765545121, COSV56389320; called by muse, mutect2, varscan2
- UPF1 | c.3280C>T p.L1094F (on ENST00000599848 / NM_001297549.2; = p.L1083F on NM_002911.4) | Missense Mutation (SNP) | VAF 85/248 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as COSV53199463; called by muse, mutect2, varscan2
- UQCRQ | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 148/247 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as rs1392129460; called by muse, mutect2, varscan2
- VEGFC | c.281G>A p.R94K | Missense Mutation (SNP) | VAF 154/408 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99710332; called by muse, mutect2, varscan2
- VN1R2 | c.824G>A p.G275E | Missense Mutation (SNP) | VAF 154/372 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.807); catalogued as COSV59037760; called by muse, mutect2, varscan2
- VPS13A | c.6008C>T p.S2003L | Missense Mutation (SNP) | VAF 77/253 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.56); catalogued as rs773356967; called by muse, mutect2, varscan2
- VSX2 | c.776C>T p.S259L | Missense Mutation (SNP) | VAF 106/325 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs751455710, COSV56217112; called by muse, mutect2, varscan2
- VWA5B1 | c.1572G>A p.K524= | Splice Region (SNP) | VAF 96/283 reads (34%) | catalogued as rs1326419266, COSV57056120; called by muse, mutect2, varscan2
- VWDE | c.3829G>A p.D1277N | Missense Mutation (SNP) | VAF 83/268 reads (31%) | SIFT tolerated (0.65); PolyPhen benign (0.051); catalogued as rs1455056273, COSV51724716; called by muse, mutect2
- WDR49 | c.2017G>A p.E673K (on ENST00000308378 / NM_001366158.1; = p.E1014K on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 98/300 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.439); catalogued as rs1373560612, COSV52984038; called by muse, mutect2, varscan2
- WDR87 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 89/269 reads (33%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.669); catalogued as COSV58198479; called by muse, mutect2, varscan2
- XAGE5 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 140/189 reads (74%) | SIFT deleterious (0.05); PolyPhen benign (0.099); catalogued as rs782167993, COSV63567669; called by muse, mutect2, varscan2
- ZAN | c.273G>A p.M91I | Missense Mutation (SNP) | VAF 97/638 reads (15%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.959); catalogued as rs1302864034; called by muse, mutect2, varscan2
- ZBED9 | c.1553C>T p.P518L | Missense Mutation (SNP) | VAF 127/425 reads (30%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs759969184; called by muse, mutect2, varscan2
- ZDHHC2 | c.994C>T p.Q332* | Nonsense Mutation (SNP) | VAF 150/246 reads (61%) | catalogued as rs866808863; called by muse, mutect2, varscan2
- ZFPM2 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 117/265 reads (44%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.453); catalogued as rs747694879, COSV101343025, COSV68281404; called by muse, mutect2, varscan2
- ZNF20 | c.1559C>T p.S520L | Missense Mutation (SNP) | VAF 131/348 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV61999104; called by muse, mutect2, varscan2
- ZNF208 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 109/309 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.076); catalogued as rs779654274, COSV68099574, COSV68106324; called by muse, mutect2, varscan2
- ZNF415 | c.932G>A p.R311Q | Missense Mutation (SNP) | VAF 126/355 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs199811601; called by muse, mutect2, varscan2
- ZNF417 | c.1499C>T p.S500L | Missense Mutation (SNP) | VAF 162/348 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as rs771332107, COSV100364182; called by muse, mutect2, varscan2
- ZNF479 | c.1118G>A p.R373K | Missense Mutation (SNP) | VAF 164/480 reads (34%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.911); catalogued as COSV58637105, COSV58641735; called by muse, mutect2
- ZNF554 | c.1309G>A p.E437K | Missense Mutation (SNP) | VAF 174/472 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.119); catalogued as rs777244317, COSV57885546; called by muse, mutect2, varscan2
- ZNF644 | c.1444C>T p.R482C | Missense Mutation (SNP) | VAF 128/333 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1423852081, COSV61346562; called by muse, mutect2, varscan2
- ZNF665 | c.325C>T p.R109* (on ENST00000600412; = p.R174* on NM_024733.5 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 166/414 reads (40%) | catalogued as rs1042133945; called by muse, mutect2, varscan2
- ZNF804A | c.3394C>T p.L1132F | Missense Mutation (SNP) | VAF 115/233 reads (49%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.896); catalogued as COSV56440746, COSV56463365; called by muse, mutect2, varscan2
- ZNF835 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 213/583 reads (37%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs760238869, COSV73379264; called by muse, mutect2
- ZSCAN4 | c.350G>A p.R117K | Missense Mutation (SNP) | VAF 113/311 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100552430, COSV59001765; called by muse, mutect2, varscan2
- AAAS | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 133/353 reads (38%) | SIFT tolerated (0.85); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- ABCA2 | c.3316C>T p.L1106F (on ENST00000614293; = p.L1076F on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 146/399 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AC099489.1 | c.8642G>A p.R2881Q | Missense Mutation (SNP) | VAF 163/504 reads (32%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- AC233723.1 | c.100C>T p.P34S | Missense Mutation (SNP) | VAF 129/233 reads (55%) | PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- ACAA2 | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 108/337 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- ADAM7 | c.231C>T p.S77= | Splice Region (SNP) | VAF 45/92 reads (49%) | called by muse, mutect2, varscan2
- ADAMTS20 | c.5132C>T p.S1711L | Missense Mutation (SNP) | VAF 88/227 reads (39%) | SIFT tolerated (0.77); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ADAMTS4 | c.2496del p.W833Gfs*35 | Frame Shift Del (DEL) | VAF 110/344 reads (32%) | called by mutect2, varscan2
- ADAMTS4 | c.1432G>T p.G478C | Missense Mutation (SNP) | VAF 208/670 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- ADGRA1 | c.692C>T p.A231V | Missense Mutation (SNP) | VAF 170/280 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ADGRL3 | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 131/409 reads (32%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- AKAP6 | c.662G>A p.G221D | Missense Mutation (SNP) | VAF 127/318 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AKAP8 | c.547C>T p.L183F | Missense Mutation (SNP) | VAF 214/587 reads (36%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- AKR1D1 | c.967C>T p.H323Y | Missense Mutation (SNP) | VAF 82/563 reads (15%) | SIFT tolerated (0.81); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- AL441992.2 | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 152/401 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AL645922.1 | c.1097G>A p.R366K | Missense Mutation (SNP) | VAF 184/447 reads (41%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ALCAM | c.1276C>T p.P426S | Missense Mutation (SNP) | VAF 113/309 reads (37%) | SIFT tolerated (0.74); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- AMPH | c.1706C>T p.T569I | Missense Mutation (SNP) | VAF 142/402 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ANKFN1 | c.529C>T p.P177S | Missense Mutation (SNP) | VAF 164/457 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- ANKRD18A | c.1968G>A p.W656* | Nonsense Mutation (SNP) | VAF 86/131 reads (66%) | called by muse, mutect2, varscan2
- ANKRD30A | c.1068A>T p.E356D (on ENST00000611781; = p.E300D on NM_052997.2) | Missense Mutation (SNP) | VAF 170/453 reads (38%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- ANKRD30BL | c.190G>A p.D64N | Missense Mutation (SNP) | VAF 63/164 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ANKRD55 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 119/358 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARFGEF3 | c.2866G>A p.A956T | Missense Mutation (SNP) | VAF 85/152 reads (56%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARMC4 | c.2743_2744dup p.L915Ffs*2 | Frame Shift Ins (INS) | VAF 147/421 reads (35%) | called by mutect2, pindel, varscan2
- ARPC4 | c.20C>T p.P7L | Missense Mutation (SNP) | VAF 121/343 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ASTN2 | c.3880C>T p.P1294S (on ENST00000313400 / NM_001365069.1; = p.P1243S on NM_014010.5) | Missense Mutation (SNP) | VAF 125/356 reads (35%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- ATP10A | c.3478G>A p.G1160S | Missense Mutation (SNP) | VAF 97/272 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- ATP13A5 | c.71T>C p.F24S | Missense Mutation (SNP) | VAF 127/278 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP6V1E2 | c.424C>T p.L142F | Missense Mutation (SNP) | VAF 162/401 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ATXN7L1 | c.1314T>G p.S438R | Missense Mutation (SNP) | VAF 162/898 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AUP1 | c.283A>T p.N95Y | Missense Mutation (SNP) | VAF 146/384 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BAG6 | c.3179T>C p.V1060A (on ENST00000676571; = p.V1013A on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 179/475 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- BBS12 | c.2048T>C p.V683A | Missense Mutation (SNP) | VAF 95/245 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, varscan2
- BRSK1 | c.376G>A p.G126R | Missense Mutation (SNP) | VAF 133/405 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- BRSK1 | c.377G>A p.G126E | Missense Mutation (SNP) | VAF 133/404 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- C12orf29 | c.593G>A p.G198E | Missense Mutation (SNP) | VAF 102/258 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C16orf96 | c.2174C>T p.S725F | Missense Mutation (SNP) | VAF 151/358 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- C19orf18 | c.221C>T p.S74F | Missense Mutation (SNP) | VAF 110/274 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- C2orf78 | c.628C>T p.Q210* | Nonsense Mutation (SNP) | VAF 174/513 reads (34%) | called by muse, mutect2, varscan2
- C3orf20 | c.185C>A p.T62N | Missense Mutation (SNP) | VAF 181/511 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- CACNA1E | c.1516C>A p.H506N | Missense Mutation (SNP) | VAF 109/276 reads (39%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNA2D3 | c.3175C>A p.H1059N | Missense Mutation (SNP) | VAF 132/351 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CAMK4 | c.1348C>T p.P450S | Missense Mutation (SNP) | VAF 158/262 reads (60%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CAPZA3 | c.522G>A p.W174* | Nonsense Mutation (SNP) | VAF 170/453 reads (38%) | called by muse, mutect2, varscan2
- CASKIN1 | c.1288G>A p.G430R | Missense Mutation (SNP) | VAF 145/357 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.442); called by muse, mutect2, varscan2
- CASP1 | c.410C>T p.S137F (on ENST00000436863 / NM_033292.4; = p.S116F on NM_001223.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 71/215 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- CATSPERB | c.59C>T p.S20L | Missense Mutation (SNP) | VAF 62/220 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- CCNK | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 164/431 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CD300C | c.454C>T p.P152S | Missense Mutation (SNP) | VAF 158/403 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- CDC27 | c.1631G>C p.W544S | Missense Mutation (SNP) | VAF 127/343 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDC42BPG | c.2663C>T p.S888F | Missense Mutation (SNP) | VAF 205/497 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDH10 | c.1279G>A p.D427N | Missense Mutation (SNP) | VAF 85/224 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- CDH16 | c.2102C>T p.P701L | Missense Mutation (SNP) | VAF 164/423 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- CDH2 | c.183C>G p.S61R | Missense Mutation (SNP) | VAF 82/209 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0.001); called by muse, varscan2
- CFAP69 | c.2108C>T p.P703L | Missense Mutation (SNP) | VAF 121/719 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CGB2 | c.430C>T p.P144S | Missense Mutation (SNP) | VAF 105/464 reads (23%) | SIFT tolerated, low confidence (0.83); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CHD9 | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 198/515 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.725); called by muse, mutect2
- CNST | c.355G>A p.G119R | Missense Mutation (SNP) | VAF 121/294 reads (41%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- CNTN5 | c.605G>A p.R202K | Missense Mutation (SNP) | VAF 137/370 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- COL28A1 | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 127/332 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- COL2A1 | c.3613C>T p.P1205S | Missense Mutation (SNP) | VAF 143/346 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- CPAMD8 | c.328C>T p.Q110* (on ENST00000651564; = p.Q63* on NM_015692.5) | Nonsense Mutation (SNP) | VAF 153/436 reads (35%) | called by muse, mutect2, varscan2
- CPM | c.211A>G p.I71V | Missense Mutation (SNP) | VAF 166/398 reads (42%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2, varscan2
- CRIM1 | c.260G>A p.G87E | Missense Mutation (SNP) | VAF 234/546 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- CRNN | c.1309G>A p.V437M | Missense Mutation (SNP) | VAF 214/498 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.705); called by muse, mutect2, varscan2
- CROCC | c.4570G>A p.E1524K | Missense Mutation (SNP) | VAF 112/314 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- CRTC1 | c.1391C>T p.S464F | Missense Mutation (SNP) | VAF 195/469 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- CYP3A7 | c.1306G>A p.G436R | Missense Mutation (SNP) | VAF 451/733 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DAB1 | c.167G>T p.R56L | Missense Mutation (SNP) | VAF 135/375 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DAO | c.35G>A p.G12E | Missense Mutation (SNP) | VAF 128/361 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DBT | c.947C>T p.S316F | Missense Mutation (SNP) | VAF 114/285 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DDAH2 | c.82G>A p.G28S | Missense Mutation (SNP) | VAF 200/588 reads (34%) | SIFT tolerated (0.74); PolyPhen benign (0.429); called by muse, mutect2, varscan2
- DDX4 | c.2122G>A p.G708R | Missense Mutation (SNP) | VAF 133/355 reads (37%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- DEFB118 | c.94G>A p.G32R | Missense Mutation (SNP) | VAF 135/360 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- DNAH11 | c.10099G>A p.E3367K | Missense Mutation (SNP) | VAF 165/453 reads (36%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- DNAH3 | c.9556G>A p.A3186T | Missense Mutation (SNP) | VAF 59/394 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- DNAH8 | c.4855A>T p.T1619S | Missense Mutation (SNP) | VAF 99/336 reads (29%) | SIFT tolerated (0.7); PolyPhen benign (0.102); called by muse, mutect2
- DNAH8 | c.8782C>T p.P2928S | Missense Mutation (SNP) | VAF 173/428 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- DNAJB11 | c.401T>A p.I134N | Missense Mutation (SNP) | VAF 107/307 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- DNAJC14 | c.473C>T p.T158I | Missense Mutation (SNP) | VAF 111/326 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- DNPH1 | c.198G>A p.G66= | Splice Region (SNP) | VAF 116/350 reads (33%) | called by muse, mutect2, varscan2
- DNPH1 | c.197G>T p.G66V | Missense Mutation (SNP) | VAF 116/347 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DOCK4 | c.1178A>C p.N393T | Missense Mutation (SNP) | VAF 223/353 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- DPP4 | c.1373C>T p.S458F | Missense Mutation (SNP) | VAF 142/369 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- DRC7 | c.2282G>A p.G761E | Missense Mutation (SNP) | VAF 187/476 reads (39%) | SIFT tolerated (1); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- DZIP1 | c.1412C>T p.A471V | Missense Mutation (SNP) | VAF 121/332 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- EHBP1L1 | c.842C>T p.P281L | Missense Mutation (SNP) | VAF 126/357 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- ELOA2 | c.805G>A p.A269T | Missense Mutation (SNP) | VAF 162/445 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.034); called by muse, mutect2
- ELOA2 | c.804G>A p.W268* | Nonsense Mutation (SNP) | VAF 163/444 reads (37%) | called by muse, mutect2
- ELP6 | c.307C>T p.P103S | Missense Mutation (SNP) | VAF 121/322 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- EPB41L4A | c.1262+1G>A p.X421_splice | Splice Site (SNP) | VAF 97/169 reads (57%) | called by muse, mutect2, varscan2
- EPB41L4A | c.1262G>A p.S421N | Missense Mutation (SNP) | VAF 97/172 reads (56%) | SIFT tolerated (0.11); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- EPM2AIP1 | c.1217C>A p.A406D | Missense Mutation (SNP) | VAF 161/449 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- EPM2AIP1 | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 84/244 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- EPS8L1 | c.1435G>A p.A479T (on ENST00000201647 / NM_133180.3; = p.A352T on NM_017729.3) | Missense Mutation (SNP) | VAF 110/299 reads (37%) | SIFT tolerated (0.43); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ERBB4 | c.3592G>A p.A1198T | Missense Mutation (SNP) | VAF 189/441 reads (43%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- ESRP1 | c.865C>T p.H289Y | Missense Mutation (SNP) | VAF 138/431 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- F11R | c.583G>A p.G195R | Missense Mutation (SNP) | VAF 109/286 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- F3 | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 189/475 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- FAM153B | c.267G>A p.M89I (on ENST00000253490; = p.M12I on NM_001265615.1) | Missense Mutation (SNP) | VAF 71/239 reads (30%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- FAM160A2 | c.1760C>T p.P587L (on ENST00000449352 / NM_001098794.2; = p.P601L on NM_032127.4) | Missense Mutation (SNP) | VAF 192/486 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0); called by mutect2, varscan2
- FAM171A2 | c.1729C>T p.P577S | Missense Mutation (SNP) | VAF 134/352 reads (38%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- FAM172A | c.829C>T p.H277Y | Missense Mutation (SNP) | VAF 120/289 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FANCE | c.1051C>T p.L351F | Missense Mutation (SNP) | VAF 173/467 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FBN1 | c.35G>A p.G12E | Missense Mutation (SNP) | VAF 136/381 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- FBXO8 | c.565C>T p.L189F | Missense Mutation (SNP) | VAF 64/179 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- FCGR3B | c.652C>T p.L218F | Missense Mutation (SNP) | VAF 158/641 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FGA | c.1313G>A p.G438E | Missense Mutation (SNP) | VAF 128/329 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FNBP1 | c.657G>A p.M219I | Missense Mutation (SNP) | VAF 94/259 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.409); called by muse, mutect2, varscan2
- FNDC1 | c.4508C>T p.P1503L | Missense Mutation (SNP) | VAF 226/352 reads (64%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- FRAS1 | c.128C>T p.P43L | Missense Mutation (SNP) | VAF 89/230 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- GAB1 | c.1364C>T p.P455L | Missense Mutation (SNP) | VAF 142/395 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- GAL3ST2 | c.1190G>A p.G397E | Missense Mutation (SNP) | VAF 112/368 reads (30%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GAREM1 | c.2405G>A p.W802* (on ENST00000269209 / NM_001242409.2; = p.W801* on NM_022751.3) | Nonsense Mutation (SNP) | VAF 178/445 reads (40%) | called by muse, mutect2, varscan2
- GARRE1 | c.2938C>T p.P980S | Missense Mutation (SNP) | VAF 190/538 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GBGT1 | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 170/445 reads (38%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- GDAP2 | c.1059G>A p.M353I | Missense Mutation (SNP) | VAF 120/329 reads (36%) | SIFT tolerated (0.59); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- GJA8 | c.56C>T p.T19I | Missense Mutation (SNP) | VAF 104/316 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- GJD2 | c.12G>A p.W4* | Nonsense Mutation (SNP) | VAF 109/351 reads (31%) | called by muse, mutect2, varscan2
- GK | c.842C>A p.A281D (on ENST00000427190 / NM_001205019.2; = p.A275D on NM_000167.6) | Missense Mutation (SNP) | VAF 100/145 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GLCCI1 | c.334C>T p.P112S | Missense Mutation (SNP) | VAF 84/173 reads (49%) | SIFT tolerated (0.66); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- GLI2 | c.2938C>T p.P980S (on ENST00000361492 / NM_001374353.1; = p.P997S on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 236/594 reads (40%) | SIFT tolerated (0.65); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- GLT1D1 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 154/386 reads (40%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GPRIN1 | c.2678C>T p.P893L | Missense Mutation (SNP) | VAF 209/354 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- GRK1 | c.1522G>A p.E508K | Missense Mutation (SNP) | VAF 174/428 reads (41%) | SIFT tolerated (1); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- GRM2 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 172/429 reads (40%) | SIFT tolerated (0.92); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- GRM3 | c.1514C>A p.P505H | Missense Mutation (SNP) | VAF 114/622 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRM5 | c.671G>A p.G224E | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GTF2H2C | c.64C>T p.L22F | Missense Mutation (SNP) | VAF 61/181 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- GTF2IRD1 | c.1319A>C p.D440A | Missense Mutation (SNP) | VAF 62/545 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- GTPBP4 | c.1894G>A p.D632N | Missense Mutation (SNP) | VAF 85/281 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GUCY2F | c.1794G>A p.M598I | Missense Mutation (SNP) | VAF 90/123 reads (73%) | SIFT tolerated (0.3); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- HCFC2 | c.526G>A p.G176S | Missense Mutation (SNP) | VAF 179/448 reads (40%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HEATR4 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 132/377 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- HIVEP2 | c.2498C>T p.P833L | Missense Mutation (SNP) | VAF 177/275 reads (64%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- HORMAD1 | c.587G>A p.G196D | Missense Mutation (SNP) | VAF 127/372 reads (34%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- HR | c.2252G>A p.G751E | Missense Mutation (SNP) | VAF 215/356 reads (60%) | SIFT tolerated (0.05); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- HRC | c.1705G>A p.E569K | Missense Mutation (SNP) | VAF 230/574 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.08); called by muse, varscan2
- HSH2D | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 89/229 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- IDO2 | c.955G>A p.D319N (on ENST00000389060; = p.D332N on NM_194294.2) | Missense Mutation (SNP) | VAF 137/330 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- IGHG1 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 194/522 reads (37%) | SIFT tolerated (0.35); PolyPhen benign (0.046); called by muse, mutect2
- IL17RD | c.1592G>A p.R531K | Missense Mutation (SNP) | VAF 159/441 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- IL18R1 | c.368G>A p.R123K | Missense Mutation (SNP) | VAF 75/249 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- IL1F10 | c.325G>C p.A109P | Missense Mutation (SNP) | VAF 153/397 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- IQCN | c.1295C>T p.S432F | Missense Mutation (SNP) | VAF 202/531 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- IRAG2 | c.3533A>C p.K1178T (on ENST00000636465; = p.K223T on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 144/404 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- JAM2 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 121/309 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNK1 | c.386G>A p.G129E | Missense Mutation (SNP) | VAF 134/351 reads (38%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- KCNK9 | c.835C>T p.P279S | Missense Mutation (SNP) | VAF 208/681 reads (31%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNT1 | c.1424C>T p.P475L (on ENST00000488444; = p.P494L on NM_020822.3) | Missense Mutation (SNP) | VAF 142/370 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- KERA | c.297G>A p.W99* | Nonsense Mutation (SNP) | VAF 125/371 reads (34%) | called by muse, mutect2, varscan2
- KIF21B | c.4603G>A p.E1535K (on ENST00000422435 / NM_001252100.2; = p.E1522K on NM_017596.4) | Missense Mutation (SNP) | VAF 95/291 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KLHL1 | c.2154A>C p.E718D | Missense Mutation (SNP) | VAF 103/327 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLHL13 | c.1412T>C p.V471A | Missense Mutation (SNP) | VAF 164/220 reads (75%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- KMT2E | c.3352G>A p.E1118K | Missense Mutation (SNP) | VAF 169/764 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- KPNA2 | c.506C>T p.S169F | Missense Mutation (SNP) | VAF 155/450 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- KRT12 | c.587G>A p.G196E | Missense Mutation (SNP) | VAF 184/456 reads (40%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- KRT19 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 97/257 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- LAMA2 | c.768G>A p.M256I | Missense Mutation (SNP) | VAF 134/220 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- LARS2 | c.1261G>A p.D421N | Missense Mutation (SNP) | VAF 82/245 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LPIN1 | c.1145C>T p.S382F | Missense Mutation (SNP) | VAF 81/238 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- LRRC1 | c.1127C>T p.S376F | Missense Mutation (SNP) | VAF 117/285 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); called by muse, mutect2, varscan2
- LRRC7 | c.4244T>A p.I1415N (on ENST00000651989 / NM_001370785.2; = p.I1335N on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 96/294 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- LRRC74A | c.371C>T p.A124V | Missense Mutation (SNP) | VAF 109/304 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- LRRC9 | c.1538C>T p.S513F | Missense Mutation (SNP) | VAF 88/243 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- LRSAM1 | c.151A>C p.T51P | Missense Mutation (SNP) | VAF 127/395 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LRSAM1 | c.152C>T p.T51I | Missense Mutation (SNP) | VAF 128/397 reads (32%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MAGEC1 | c.1525T>A p.F509I | Missense Mutation (SNP) | VAF 216/276 reads (78%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.04); called by muse, varscan2
- MANEA | c.1247C>T p.P416L | Missense Mutation (SNP) | VAF 108/165 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MARK3 | c.1622C>T p.T541I | Missense Mutation (SNP) | VAF 120/295 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- MDGA2 | c.2371A>G p.K791E (on ENST00000399232 / NM_001113498.2; = p.K493E on NM_182830.4) | Missense Mutation (SNP) | VAF 104/305 reads (34%) | SIFT tolerated (0.71); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- MED12L | c.1679C>T p.S560F | Missense Mutation (SNP) | VAF 95/292 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MED17 | c.1025C>T p.S342F | Missense Mutation (SNP) | VAF 99/234 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- MEIOC | c.961G>A p.E321K | Missense Mutation (SNP) | VAF 88/267 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- MEP1A | c.1301G>A p.G434E | Missense Mutation (SNP) | VAF 167/425 reads (39%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.764); called by muse, mutect2, varscan2
- MGAM2 | c.2822C>T p.P941L | Missense Mutation (SNP) | VAF 237/398 reads (60%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- MMP27 | c.318G>A p.W106* | Nonsense Mutation (SNP) | VAF 136/392 reads (35%) | called by muse, mutect2, varscan2
- MORN1 | c.83G>C p.G28A | Missense Mutation (SNP) | VAF 95/267 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MROH2B | c.4491A>T p.K1497N | Missense Mutation (SNP) | VAF 137/310 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- MROH7 | c.1978G>A p.E660K | Missense Mutation (SNP) | VAF 114/305 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- MUC12 | c.5267C>T p.S1756F (on ENST00000379442; = p.S1613F on NM_001164462.1) | Missense Mutation (SNP) | VAF 204/705 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- MUC16 | c.35180C>T p.A11727V | Missense Mutation (SNP) | VAF 197/509 reads (39%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MUC16 | c.30356C>T p.S10119F | Missense Mutation (SNP) | VAF 119/326 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- MUC16 | c.14059G>A p.G4687R | Missense Mutation (SNP) | VAF 163/411 reads (40%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- MUC19 | c.1001G>A p.R334K | Missense Mutation (SNP) | VAF 113/294 reads (38%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- MYBPC1 | c.2593G>A p.G865R (on ENST00000550270 / NM_206820.2; = p.G872R on NM_002465.4) | Missense Mutation (SNP) | VAF 65/171 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYL6B | c.476G>A p.G159D | Missense Mutation (SNP) | VAF 147/407 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MYO10 | c.4330C>T p.L1444F | Missense Mutation (SNP) | VAF 157/377 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- MYO6 | c.1330C>A p.P444T | Missense Mutation (SNP) | VAF 128/222 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- NCAN | c.3934G>A p.D1312N | Missense Mutation (SNP) | VAF 151/432 reads (35%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.706); called by muse, varscan2
- NCOR2 | c.3483G>A p.L1161= | Splice Region (SNP) | VAF 129/364 reads (35%) | called by muse, mutect2, varscan2
- NDC1 | c.1025C>T p.S342F | Missense Mutation (SNP) | VAF 164/411 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NEB | c.6634C>T p.Q2212* | Nonsense Mutation (SNP) | VAF 149/394 reads (38%) | called by muse, mutect2, varscan2
- NECTIN4 | c.1319C>T p.P440L | Missense Mutation (SNP) | VAF 88/261 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.604); called by muse, mutect2, varscan2
- NLRP3 | c.281C>T p.S94L | Missense Mutation (SNP) | VAF 103/263 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLRP7 | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 265/736 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.093); called by muse, mutect2
- NMNAT3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 105/243 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- NRXN3 | c.1621G>A p.E541K (on ENST00000335750 / NM_001330195.2; = p.E168K on NM_004796.6) | Missense Mutation (SNP) | VAF 111/341 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- NT5C1B | c.667G>A p.E223K (on ENST00000359846 / NM_001199086.2; = p.E163K on NM_033253.4) | Missense Mutation (SNP) | VAF 179/440 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- NT5DC2 | c.535C>T p.P179S | Missense Mutation (SNP) | VAF 65/208 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- NTNG2 | c.335G>A p.W112* | Nonsense Mutation (SNP) | VAF 180/483 reads (37%) | called by muse, mutect2, varscan2
- NUP160 | c.1300C>T p.P434S | Missense Mutation (SNP) | VAF 99/288 reads (34%) | SIFT tolerated (0.55); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- OPA3 | c.367C>T p.R123W | Missense Mutation (SNP) | VAF 173/453 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.731); called by muse, varscan2
- OPCML | c.507G>A p.W169* | Nonsense Mutation (SNP) | VAF 105/376 reads (28%) | called by muse, mutect2, varscan2
- OPRD1 | c.689C>T p.T230I | Missense Mutation (SNP) | VAF 217/549 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- OR11H4 | c.355A>G p.T119A | Missense Mutation (SNP) | VAF 133/376 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- OR2M3 | c.730C>A p.H244N | Missense Mutation (SNP) | VAF 163/444 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- OR4K3 | c.767C>T p.S256L | Missense Mutation (SNP) | VAF 105/500 reads (21%) | called by muse, mutect2, varscan2
- OR56B1 | c.7C>T p.H3Y | Missense Mutation (SNP) | VAF 71/208 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR5H6 | c.170G>A p.G57E (on ENST00000642105; = p.G41E on NM_001005479.2) | Missense Mutation (SNP) | VAF 150/416 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OTOL1 | c.500G>A p.G167E | Missense Mutation (SNP) | VAF 127/351 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCDH11X | c.206C>G p.T69S | Missense Mutation (SNP) | VAF 227/286 reads (79%) | SIFT tolerated (0.78); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- PCDHA4 | c.349T>A p.F117I | Missense Mutation (SNP) | VAF 150/254 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.416); called by muse, mutect2
- PCDHB1 | c.775T>A p.S259T | Missense Mutation (SNP) | VAF 123/242 reads (51%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PES1 | c.223C>T p.H75Y | Missense Mutation (SNP) | VAF 150/392 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PIGN | c.1892C>T p.S631F | Missense Mutation (SNP) | VAF 141/359 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- PIK3R4 | c.695G>A p.R232K | Missense Mutation (SNP) | VAF 122/306 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- PLAGL1 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 184/260 reads (71%) | SIFT deleterious (0); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- PLEK | c.509C>T p.S170F | Missense Mutation (SNP) | VAF 104/348 reads (30%) | SIFT tolerated (0.73); PolyPhen benign (0.407); called by muse, mutect2, varscan2
- PLEKHD1 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 132/372 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PLIN4 | c.3683C>T p.P1228L (on ENST00000301286; = p.P1243L on NM_001367868.2) | Missense Mutation (SNP) | VAF 132/315 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- PMFBP1 | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 172/467 reads (37%) | SIFT tolerated (0.38); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- POLE | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 140/402 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- POLQ | c.3338C>T p.S1113L | Missense Mutation (SNP) | VAF 87/245 reads (36%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- POM121L2 | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 147/390 reads (38%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- PPA2 | c.457C>T p.H153Y | Missense Mutation (SNP) | VAF 120/307 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- PPP1R14B | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 16/417 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.037); called by muse, mutect2
- PRC1 | c.209C>T p.S70F | Missense Mutation (SNP) | VAF 99/319 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- PRDM4 | c.309T>G p.S103R | Missense Mutation (SNP) | VAF 85/304 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PRKG1 | c.1864A>T p.K622* | Nonsense Mutation (SNP) | VAF 65/116 reads (56%) | called by muse, mutect2, varscan2
- PRMT8 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 141/340 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PROX1 | c.677C>T p.S226L | Missense Mutation (SNP) | VAF 175/421 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- PRR35 | c.1159G>A p.G387S | Missense Mutation (SNP) | VAF 249/557 reads (45%) | SIFT tolerated (0.75); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PRR7 | c.622C>T p.R208W | Missense Mutation (SNP) | VAF 178/325 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- PRRC2C | c.1118C>T p.S373F (on ENST00000367742; = p.S371F on NM_015172.4) | Missense Mutation (SNP) | VAF 168/444 reads (38%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRRT4 | c.794C>T p.S265F | Missense Mutation (SNP) | VAF 399/629 reads (63%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRSS16 | c.320C>T p.P107L | Missense Mutation (SNP) | VAF 136/322 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- PSD4 | c.1480G>A p.E494K | Missense Mutation (SNP) | VAF 160/419 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- PSMD14 | c.465T>G p.V155= | Splice Region (SNP) | VAF 79/232 reads (34%) | called by muse, mutect2, varscan2
- PTCRA | c.571C>T p.L191F | Missense Mutation (SNP) | VAF 248/581 reads (43%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PTDSS2 | c.1042C>T p.L348F | Missense Mutation (SNP) | VAF 248/617 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- PTPN20 | c.812T>A p.I271N | Missense Mutation (SNP) | VAF 107/187 reads (57%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- PTPRT | c.3016G>A p.E1006K | Missense Mutation (SNP) | VAF 82/244 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RAB11FIP1 | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 154/406 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RALBP1 | c.709A>G p.K237E | Missense Mutation (SNP) | VAF 98/227 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RGL2 | c.268del p.R90Dfs*25 | Frame Shift Del (DEL) | VAF 223/654 reads (34%) | called by mutect2, pindel, varscan2
- RHAG | c.133G>A p.G45S | Missense Mutation (SNP) | VAF 118/352 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- RHBDF1 | c.56G>A p.W19* | Nonsense Mutation (SNP) | VAF 220/478 reads (46%) | called by muse, mutect2
- RIMS2 | c.2629G>A p.E877K (on ENST00000666250 / NM_001348490.2; = p.E685K on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 100/316 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- RIPPLY2 | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 98/161 reads (61%) | SIFT tolerated (0.26); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ROCK2 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 67/184 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- RP1 | c.2971G>A p.D991N | Missense Mutation (SNP) | VAF 128/311 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RP1 | c.3935G>A p.G1312E | Missense Mutation (SNP) | VAF 116/334 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SALL2 | c.1504G>A p.A502T | Missense Mutation (SNP) | VAF 154/461 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- SAMD9 | c.1957G>A p.E653K | Missense Mutation (SNP) | VAF 99/593 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- SBF2 | c.4555G>A p.E1519K | Missense Mutation (SNP) | VAF 72/264 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.362); called by muse, mutect2, varscan2
- SCAF11 | c.2065A>G p.T689A | Missense Mutation (SNP) | VAF 115/317 reads (36%) | SIFT tolerated (0.78); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SCAI | c.149A>C p.D50A (on ENST00000336505 / NM_001144877.3; = p.D73A on NM_173690.5) | Missense Mutation (SNP) | VAF 122/317 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SCARF2 | c.1381del p.L461Sfs*42 | Frame Shift Del (DEL) | VAF 191/557 reads (34%) | called by mutect2, pindel, varscan2
- SCN4A | c.3740T>A p.M1247K | Missense Mutation (SNP) | VAF 167/410 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- SCN4A | c.3428T>G p.F1143C | Missense Mutation (SNP) | VAF 102/270 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SCN7A | c.1246C>T p.Q416* | Nonsense Mutation (SNP) | VAF 80/252 reads (32%) | called by muse, mutect2, varscan2
- SCNN1D | c.745G>A p.E249K (on ENST00000338555; = p.E413K on NM_001130413.4) | Missense Mutation (SNP) | VAF 155/393 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- SCUBE2 | c.1363C>T p.P455S | Missense Mutation (SNP) | VAF 113/315 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- SEMA3D | c.892A>C p.N298H | Missense Mutation (SNP) | VAF 425/658 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SEMA3E | c.442G>T p.G148* | Nonsense Mutation (SNP) | VAF 97/505 reads (19%) | called by mutect2, varscan2
- SI | c.3698A>T p.Y1233F | Missense Mutation (SNP) | VAF 105/272 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SIGLEC14 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 212/691 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.029); called by muse, mutect2
- SLC11A2 | c.838C>T p.P280S (on ENST00000394904 / NM_001379455.1; = p.P251S on NM_000617.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 171/425 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC12A5 | c.206C>T p.A69V (on ENST00000454036 / NM_001134771.2; = p.A46V on NM_020708.5) | Missense Mutation (SNP) | VAF 122/327 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- SLC15A4 | c.547-3_549del p.X183_splice | Splice Site (DEL) | VAF 64/189 reads (34%) | called by mutect2, pindel, varscan2
- SLC36A2 | c.1100C>T p.P367L | Missense Mutation (SNP) | VAF 184/288 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.2049-1G>A p.X683_splice (on ENST00000540229 / NM_001371097.1; = p.X622_splice on NM_001009562.4) | Splice Site (SNP) | VAF 58/155 reads (37%) | called by muse, mutect2, varscan2
- SMC1B | c.2533G>A p.G845S | Missense Mutation (SNP) | VAF 87/286 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- SMG1 | c.4745C>T p.P1582L | Missense Mutation (SNP) | VAF 102/328 reads (31%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- SMYD2 | c.274C>T p.P92S | Missense Mutation (SNP) | VAF 134/356 reads (38%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- SNX32 | c.568G>A p.D190N | Missense Mutation (SNP) | VAF 90/241 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SP140 | c.2492G>A p.R831K | Missense Mutation (SNP) | VAF 72/250 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- SPAG17 | c.4360G>A p.D1454N | Missense Mutation (SNP) | VAF 122/337 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SPAG17 | c.1124C>T p.P375L | Missense Mutation (SNP) | VAF 97/332 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SPATA3 | c.347C>T p.P116L | Missense Mutation (SNP) | VAF 175/523 reads (33%) | SIFT deleterious, low confidence (0.03); called by muse, mutect2, varscan2
- SPATA5L1 | c.1366A>T p.M456L | Missense Mutation (SNP) | VAF 150/413 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPEG | c.3445G>A p.A1149T | Missense Mutation (SNP) | VAF 150/443 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SRBD1 | c.568C>T p.P190S | Missense Mutation (SNP) | VAF 171/440 reads (39%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- SRP54 | c.58G>C p.A20P | Missense Mutation (SNP) | VAF 15/342 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); called by muse, mutect2
- SSTR4 | c.380G>A p.G127D | Missense Mutation (SNP) | VAF 157/451 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- STARD10 | c.34G>A p.G12R | Missense Mutation (SNP) | VAF 136/366 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- STK31 | c.2846C>T p.S949F | Missense Mutation (SNP) | VAF 66/211 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- STRIT1 | c.29C>T p.S10L | Missense Mutation (SNP) | VAF 122/356 reads (34%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- STXBP3 | c.644T>C p.L215P | Missense Mutation (SNP) | VAF 119/270 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SVEP1 | c.6551G>A p.S2184N | Missense Mutation (SNP) | VAF 115/356 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SYNE1 | c.16018C>T p.Q5340* (on ENST00000367255 / NM_182961.4; = p.Q5269* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 154/232 reads (66%) | called by muse, mutect2, varscan2
- SYNPO | c.2650C>T p.P884S (on ENST00000394243 / NM_001166208.2; = p.P640S on NM_007286.6) | Missense Mutation (SNP) | VAF 22/430 reads (5%) | SIFT tolerated (0.75); PolyPhen benign (0.015); called by muse, mutect2
- SYT7 | c.356C>T p.S119F | Missense Mutation (SNP) | VAF 141/351 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- TADA2A | c.1046C>T p.P349L | Missense Mutation (SNP) | VAF 169/433 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TDRD15 | c.545G>A p.G182E | Missense Mutation (SNP) | VAF 103/298 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TDRD9 | c.2701A>G p.T901A | Missense Mutation (SNP) | VAF 112/295 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- TENM2 | c.4039G>A p.G1347R (on ENST00000518659 / NM_001122679.2; = p.G1108R on NM_001080428.3) | Missense Mutation (SNP) | VAF 128/212 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TENM3 | c.2702G>A p.G901E | Missense Mutation (SNP) | VAF 62/184 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TENM4 | c.6193G>A p.D2065N | Missense Mutation (SNP) | VAF 172/462 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TENM4 | c.2991A>T p.E997D | Missense Mutation (SNP) | VAF 158/389 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- THUMPD3 | c.893T>A p.F298Y | Missense Mutation (SNP) | VAF 86/227 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- TKTL2 | c.1628C>T p.P543L | Missense Mutation (SNP) | VAF 156/397 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TLR2 | c.1729G>A p.D577N | Missense Mutation (SNP) | VAF 172/437 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- TMC5 | c.589C>T p.P197S | Missense Mutation (SNP) | VAF 137/381 reads (36%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TMEM138 | c.430C>T p.P144S | Missense Mutation (SNP) | VAF 125/350 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- TMEM232 | c.1609C>T p.P537S | Missense Mutation (SNP) | VAF 101/164 reads (62%) | SIFT tolerated (0.19); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- TMEM59L | c.692G>A p.R231K | Missense Mutation (SNP) | VAF 137/329 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- TOPAZ1 | c.3176G>A p.G1059E | Missense Mutation (SNP) | VAF 105/261 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- TRANK1 | c.1912C>T p.Q638* | Nonsense Mutation (SNP) | VAF 144/452 reads (32%) | called by muse, mutect2, varscan2
- TRANK1 | c.965G>A p.G322E | Missense Mutation (SNP) | VAF 88/280 reads (31%) | SIFT tolerated (0.78); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- TRIM24 | c.904C>T p.Q302* | Nonsense Mutation (SNP) | VAF 145/271 reads (54%) | called by muse, mutect2, varscan2
- TRIM39 | c.244C>T p.R82W | Missense Mutation (SNP) | VAF 240/605 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRIM63 | c.490C>T p.Q164* | Nonsense Mutation (SNP) | VAF 106/269 reads (39%) | called by muse, mutect2, varscan2
- TRIM69 | c.1382C>T p.T461I (on ENST00000329464 / NM_182985.5; = p.T302I on NM_080745.5) | Missense Mutation (SNP) | VAF 207/553 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- TTBK2 | c.2174G>A p.G725E | Missense Mutation (SNP) | VAF 120/347 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- TTN | c.61859G>A p.G20620E (on ENST00000591111; = p.G13196E on NM_003319.4) | Missense Mutation (SNP) | VAF 92/230 reads (40%) | PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- TTN | c.32842G>A p.V10948I (on ENST00000591111; = p.V10021I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 146/401 reads (36%) | PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TTN | c.31004C>T p.P10335L (on ENST00000591111; = p.P9408L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 107/265 reads (40%) | PolyPhen probably damaging (0.998); called by muse, varscan2
- TTN | c.6416G>A p.R2139K (on ENST00000591111; = p.R2093K on NM_003319.4) | Missense Mutation (SNP) | VAF 158/425 reads (37%) | PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- UGT1A9 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 160/432 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- UGT2A1 | c.1477G>A p.G493R | Missense Mutation (SNP) | VAF 140/448 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- UGT3A2 | c.1528G>A p.A510T | Missense Mutation (SNP) | VAF 113/327 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- UNC13A | c.3691C>T p.Q1231* | Nonsense Mutation (SNP) | VAF 118/336 reads (35%) | called by muse, mutect2, varscan2
- USP28 | c.1514C>T p.P505L | Missense Mutation (SNP) | VAF 132/389 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- VPS13C | c.2545T>G p.S849A (on ENST00000644861 / NM_020821.3; = p.S806A on NM_017684.5) | Missense Mutation (SNP) | VAF 87/240 reads (36%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDHD1 | c.2902C>T p.P968S | Missense Mutation (SNP) | VAF 88/261 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- YTHDC1 | c.1712A>T p.E571V (on ENST00000344157 / NM_001031732.4; = p.E553V on NM_133370.4) | Missense Mutation (SNP) | VAF 144/345 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- ZAN | c.2936C>T p.P979L | Missense Mutation (SNP) | VAF 214/1123 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZBTB20 | c.1547C>T p.P516L (on ENST00000474710 / NM_001164342.2; = p.P443L on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 171/481 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZC3H12C | c.797C>T p.S266F | Missense Mutation (SNP) | VAF 120/317 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZDHHC15 | c.863+1G>T p.X288_splice | Splice Site (SNP) | VAF 84/115 reads (73%) | called by muse, mutect2, varscan2
- ZNF469 | c.11197A>G p.T3733A (on ENST00000437464; = p.T3761A on NM_001367624.2) | Missense Mutation (SNP) | VAF 204/554 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- ZNF516 | c.1338C>A p.D446E | Missense Mutation (SNP) | VAF 152/409 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.742); called by muse, varscan2
- ZNF556 | c.1046G>A p.G349E | Missense Mutation (SNP) | VAF 139/404 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF568 | c.1477C>T p.Q493* | Nonsense Mutation (SNP) | VAF 151/363 reads (42%) | called by muse, mutect2, varscan2
- ZNF655 | c.674C>T p.S225L | Missense Mutation (SNP) | VAF 110/550 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- ZNF69 | c.323C>T p.P108L (on ENST00000429654 / NM_001364730.1; = p.P94L on NM_021915.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 109/324 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF703 | c.797C>G p.P266R | Missense Mutation (SNP) | VAF 209/516 reads (41%) | SIFT tolerated (0.48); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- ZNF722P | c.787C>T p.H263Y | Missense Mutation (SNP) | VAF 468/757 reads (62%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF728 | c.1756C>T p.H586Y | Missense Mutation (SNP) | VAF 118/273 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF728 | c.176G>A p.G59E | Missense Mutation (SNP) | VAF 87/291 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- ZNF75D | c.1402C>T p.Q468* | Nonsense Mutation (SNP) | VAF 198/259 reads (76%) | called by muse, mutect2, varscan2
- ZNF841 | c.739C>T p.H247Y (on ENST00000426391 / NM_001369830.1; = p.H363Y on NM_001136499.1 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 176/427 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- ZPBP | c.496G>T p.E166* | Nonsense Mutation (SNP) | VAF 58/215 reads (27%) | called by muse, mutect2, varscan2
- A4GALT | c.540C>T p.I180= | Silent (SNP) | VAF 163/408 reads (40%) | catalogued as COSV50743985; called by muse, mutect2, varscan2
- AC099489.1 | c.6828C>T p.F2276= | Silent (SNP) | VAF 149/340 reads (44%) | catalogued as rs998041610; called by muse, mutect2, varscan2
- ACOX1 | c.849C>A p.S283= | Silent (SNP) | VAF 124/375 reads (33%) | catalogued as COSV99503352; called by muse, mutect2, varscan2
- ACSS3 | c.168C>T p.S56= | Silent (SNP) | VAF 193/486 reads (40%) | catalogued as rs1311715101; called by muse, mutect2, varscan2
- ADAM18 | c.885A>G p.K295= | Silent (SNP) | VAF 86/262 reads (33%) | called by muse, mutect2, varscan2
- ADAM7 | c.1413G>A p.E471= | Silent (SNP) | VAF 174/276 reads (63%) | called by muse, mutect2, varscan2
- ADAMTS20 | c.2310G>A p.G770= | Silent (SNP) | VAF 82/214 reads (38%) | catalogued as COSV67128743; called by muse, mutect2, varscan2
- ADCY9 | c.2898G>A p.S966= | Silent (SNP) | VAF 140/398 reads (35%) | catalogued as rs769823999, COSV53577734; called by muse, mutect2, varscan2
- ADGRE1 | c.1545C>T p.V515= | Silent (SNP) | VAF 145/363 reads (40%) | called by muse, mutect2, varscan2
- AGAP1 | c.2121G>A p.E707= (on ENST00000304032 / NM_001037131.3; = p.E654= on NM_014914.5) | Silent (SNP) | VAF 92/224 reads (41%) | called by muse, mutect2, varscan2
- AGO1 | c.2187A>G p.P729= | Silent (SNP) | VAF 121/351 reads (34%) | called by muse, mutect2, varscan2
- AHDC1 | c.129C>T p.P43= | Silent (SNP) | VAF 118/331 reads (36%) | catalogued as rs754191469; called by muse, mutect2, varscan2
- AKAP8L | c.504C>T p.F168= | Silent (SNP) | VAF 152/456 reads (33%) | catalogued as rs1170646877, COSV101275748; called by muse, mutect2, varscan2
- AL441992.2 | c.69C>T p.A23= | Silent (SNP) | VAF 152/403 reads (38%) | called by muse, mutect2, varscan2
- AMPH | c.1707C>T p.T569= | Silent (SNP) | VAF 144/402 reads (36%) | catalogued as rs754650050, COSV57758845; called by muse, mutect2, varscan2
- AMY1C | c.903C>T p.F301= | Silent (SNP) | VAF 103/604 reads (17%) | catalogued as COSV100915220; called by muse, mutect2, varscan2
- ANK2 | c.10779C>T p.F3593= | Silent (SNP) | VAF 92/244 reads (38%) | catalogued as COSV52155999; called by muse, mutect2, varscan2
377 further variants in this file (0 protein-altering or splice-affecting, 342 silent, 35 other) are not listed here.
